Somatic mutation profile of cancer-model specimen HCM-CSHL-0863-C18-85A (3D Organoid, passage 5; aliquot HCM-CSHL-0863-C18-85A-01D-A88H-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0863-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Colon, NOS; Tumor grade: GX.
Specimen HCM-CSHL-0863-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d42b9fa2-b613-414d-ba07-5f76a34e1fb7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0863-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0863-C18-10A-01D-A88H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dae3d033-c88d-4484-8c9d-fe3f94aa5080

The open-access MAF lists 2,066 somatic variants for this specimen: 1,531 protein-altering or splice-affecting, 453 silent, 82 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,150, Silent 453, Frame Shift Del 208, Frame Shift Ins 81, Nonsense Mutation 54, Intron 48, In Frame Del 20, 3'UTR 15, Splice Site 10, Splice Region 6, 5'Flank 6, 5'UTR 5.

Variants (750 of 2,066; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 69/175 reads (39%) | hotspot (GDC flag); catalogued as rs587781392, CM920027, COSV57321978; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CACNA1A | c.3544dup p.L1182Pfs*38 | Frame Shift Ins (INS) | VAF 145/317 reads (46%) | catalogued as rs757953057; ClinVar: pathogenic; called by mutect2, varscan2
- CAPN3 | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 168/458 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as rs886042478, CM022771; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CDH1 | c.1137G>A p.T379= | Splice Region (SNP) | VAF 64/64 reads (100%) | catalogued as rs587783050, CS060517, COSV55733400; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CRB1 | c.2501G>A p.G834D | Missense Mutation (SNP) | VAF 119/246 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1085307972, CM1514161, COSV100958084; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CTCF | c.610dup p.T204Nfs*26 | Frame Shift Ins (INS) | VAF 102/223 reads (46%) | catalogued as rs886041997; ClinVar: pathogenic; called by mutect2, varscan2
- FKRP | c.1141dup p.A381Gfs*9 | Frame Shift Ins (INS) | VAF 335/820 reads (41%) | catalogued as rs754403441; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 144/313 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MFRP | c.3del p.H2Tfs*100 (on ENST00000449574; = p.H384Tfs*94 on NM_031433.4) | Frame Shift Del (DEL) | VAF 38/294 reads (13%) | catalogued as rs587776595; ClinVar: pathogenic; called by mutect2, varscan2
- MYH11 | c.5787-4707del | Intron (DEL) | VAF 200/446 reads (45%) | catalogued as rs747392139, COSV100257523; ClinVar: uncertain significance / benign / likely benign / likely pathogenic; called by mutect2, varscan2
- MYO15A | c.1185del p.E396Rfs*48 | Frame Shift Del (DEL) | VAF 302/772 reads (39%) | catalogued as rs772536599; ClinVar: likely pathogenic / pathogenic; called by pindel, varscan2
- NDUFS1 | c.1222C>T p.R408C | Missense Mutation (SNP) | VAF 110/276 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149271416, CM103343; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NKX3-2 | c.337del p.A113Pfs*11 | Frame Shift Del (DEL) | VAF 352/757 reads (46%) | catalogued as rs606231352, CX099329; ClinVar: pathogenic; called by mutect2, varscan2
- PAFAH1B1 | c.265C>T p.R89* | Nonsense Mutation (SNP) | VAF 158/332 reads (48%) | catalogued as rs587784258, CM003040; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIGO | c.2191dup p.R731Pfs*62 | Frame Shift Ins (INS) | VAF 251/510 reads (49%) | catalogued as rs760848629; ClinVar: pathogenic; called by mutect2, varscan2
- PRUNE1 | c.316G>A p.D106N | Missense Mutation (SNP) | VAF 126/265 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773618224, CM1512541; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SLC19A3 | c.597del p.H200Mfs*8 | Frame Shift Del (DEL) | VAF 165/378 reads (44%) | catalogued as rs773140674; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TBCK | c.1370del p.N457Tfs*15 (on ENST00000273980 / NM_001163436.4; = p.N394Tfs*15 on NM_033115.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 66/158 reads (42%) | catalogued as rs746860249, CD164312; ClinVar: pathogenic; called by mutect2, varscan2
- TELO2 | c.1826G>A p.R609H | Missense Mutation (SNP) | VAF 208/459 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754162070, CM166747, COSV51976862; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- VWF | c.7450G>A p.V2484I | Missense Mutation (SNP) | VAF 26/488 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.442); catalogued as rs139864572; ClinVar: likely pathogenic; called by muse, mutect2
- ABCA1 | c.2080_2082del p.L694del | In Frame Del (DEL) | VAF 110/226 reads (49%) | catalogued as rs387906412; called by pindel, varscan2
- ABCA2 | c.3172G>A p.G1058R (on ENST00000614293; = p.G1028R on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 201/436 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1466982406; called by muse, mutect2, varscan2
- ABCA6 | c.917dup p.L306Ffs*44 | Frame Shift Ins (INS) | VAF 46/106 reads (43%) | catalogued as rs750282619; called by mutect2, varscan2
- ABCA7 | c.1643G>A p.R548Q | Missense Mutation (SNP) | VAF 31/442 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1269893155, COSV99566705; called by muse, mutect2
- ABCB5 | c.1600G>A p.A534T (on ENST00000404938 / NM_001163941.2; = p.A89T on NM_178559.6) | Missense Mutation (SNP) | VAF 220/410 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.366); catalogued as rs745873483, COSV51704716; called by muse, mutect2
- ABO | c.997G>A p.A333T | Missense Mutation (SNP) | VAF 293/672 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs369695939; called by muse, mutect2, varscan2
- ABRA | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 180/428 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as rs766328261, COSV61732065; called by muse, mutect2, varscan2
- AC006059.2 | c.103C>T p.R35W | Missense Mutation (SNP) | VAF 137/372 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs113601691; called by muse, mutect2, varscan2
- AC008676.3 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 221/495 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.059); catalogued as rs147986877, COSV104394935; called by muse, mutect2, varscan2
- AC025287.4 | c.1181G>A p.C394Y | Missense Mutation (SNP) | VAF 112/270 reads (41%) | catalogued as rs925614798; called by muse, mutect2, varscan2
- ACBD3 | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 37/531 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as rs147538215; called by muse, mutect2
- ACLY | c.428G>A p.G143D | Missense Mutation (SNP) | VAF 249/559 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1414754152; called by muse, mutect2, varscan2
- ACTN2 | c.2648C>T p.A883V | Missense Mutation (SNP) | VAF 208/435 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as rs769564893, COSV63974526; called by muse, mutect2, varscan2
- ACTRT2 | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 226/438 reads (52%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs369285757; called by muse, mutect2, varscan2
- ADAM15 | c.2324C>T p.P775L | Missense Mutation (SNP) | VAF 316/622 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1248279083; called by muse, mutect2, varscan2
- ADAMTS20 | c.2355del p.E786Kfs*86 | Frame Shift Del (DEL) | VAF 98/282 reads (35%) | catalogued as rs1177283960; called by mutect2, pindel, varscan2
- ADAMTS5 | c.2696C>T p.T899M | Missense Mutation (SNP) | VAF 211/422 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.392); catalogued as rs368781824; called by muse, mutect2, varscan2
- ADAMTS5 | c.2477C>T p.T826M | Missense Mutation (SNP) | VAF 160/328 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs150380425; called by muse, varscan2
- ADAMTSL1 | c.2765C>T p.T922M | Missense Mutation (SNP) | VAF 299/624 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs755153311; called by muse, mutect2, varscan2
- ADCY1 | c.961G>A p.A321T | Missense Mutation (SNP) | VAF 237/476 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV52043089; called by muse, mutect2, varscan2
- ADCY9 | c.954G>A p.M318I | Missense Mutation (SNP) | VAF 200/408 reads (49%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.78); catalogued as COSV53571422, COSV53576348; called by muse, mutect2, varscan2
- ADGRF4 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 161/411 reads (39%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.517); catalogued as rs376128003; called by muse, mutect2, varscan2
- ADGRL4 | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 97/212 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.02); catalogued as rs552481994; called by muse, mutect2, varscan2
- ADGRV1 | c.5944dup p.S1982Ffs*2 | Frame Shift Ins (INS) | VAF 110/265 reads (42%) | catalogued as rs1554081619; called by mutect2, pindel, varscan2
- AFDN | c.1118C>T p.S373F | Missense Mutation (SNP) | VAF 15/445 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs1164609300; called by muse, mutect2
- AGAP1 | c.380G>C p.G127A | Missense Mutation (SNP) | VAF 146/312 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs773218170, COSV58319853, COSV58340917; called by muse, mutect2, varscan2
- AGAP1 | c.2312C>T p.T771M (on ENST00000304032 / NM_001037131.3; = p.T718M on NM_014914.5) | Missense Mutation (SNP) | VAF 234/494 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs992108060; called by muse, mutect2, varscan2
- AGO1 | c.857C>A p.P286H | Missense Mutation (SNP) | VAF 131/279 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV64596484; called by muse, mutect2, varscan2
- AHNAK2 | c.13535G>A p.R4512H | Missense Mutation (SNP) | VAF 136/330 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.885); catalogued as rs112306443; called by muse, mutect2
- AHNAK2 | c.268C>T p.R90* | Nonsense Mutation (SNP) | VAF 192/387 reads (50%) | catalogued as rs540252047, COSV60914256; called by muse, mutect2, varscan2
- AKAP6 | c.6874G>A p.A2292T | Missense Mutation (SNP) | VAF 161/333 reads (48%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.017); catalogued as rs375612537; called by muse, mutect2, varscan2
- AKAP9 | c.10145G>A p.R3382H (on ENST00000359028; = p.R3358H on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 156/307 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.291); catalogued as rs776193956, COSV62359324; called by muse, mutect2, varscan2
- AKNA | c.2830C>T p.R944W | Missense Mutation (SNP) | VAF 179/394 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs773170257; called by muse, mutect2, varscan2
- AKTIP | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 105/223 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); catalogued as rs755048837, COSV50889584; called by muse, mutect2, varscan2
- AMER2 | c.1690G>A p.G564R | Missense Mutation (SNP) | VAF 213/443 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV63437297; called by muse, mutect2, varscan2
- ANAPC2 | c.1223G>A p.R408H | Missense Mutation (SNP) | VAF 222/564 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs147941604; called by muse, mutect2, varscan2
- ANK2 | c.4555G>A p.A1519T | Missense Mutation (SNP) | VAF 148/336 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs200920714, COSV99999029; called by muse, mutect2, varscan2
- ANKMY1 | c.1583G>A p.R528Q | Missense Mutation (SNP) | VAF 49/672 reads (7%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1243761323, COSV56038261; called by muse, mutect2
- ANKRD13B | c.1420C>T p.R474C | Missense Mutation (SNP) | VAF 171/431 reads (40%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.86); catalogued as rs1456844769; called by muse, mutect2, varscan2
- ANKRD24 | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 264/552 reads (48%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs1055419943; called by muse, mutect2, varscan2
- ANKRD27 | c.1799C>T p.T600M | Missense Mutation (SNP) | VAF 99/230 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs772946463, COSV60133573; called by muse, mutect2, varscan2
- ANKRD36 | c.1361A>C p.N454T | Missense Mutation (SNP) | VAF 25/25 reads (100%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.021); catalogued as rs1278901041; called by muse, mutect2, varscan2
- ANKRD36 | c.1363A>T p.M455L | Missense Mutation (SNP) | VAF 25/25 reads (100%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs1443301160; called by muse, mutect2, varscan2
- ANKRD50 | c.2746G>A p.A916T | Missense Mutation (SNP) | VAF 168/357 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs779926917, COSV101538986; called by muse, mutect2, varscan2
- ANKS6 | c.2408C>T p.A803V | Missense Mutation (SNP) | VAF 120/249 reads (48%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as rs745689147, COSV62048815; called by muse, mutect2, varscan2
- ANO8 | c.1676C>A p.A559E | Missense Mutation (SNP) | VAF 158/351 reads (45%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.005); catalogued as rs1305996736; called by mutect2, varscan2
- ANTXR1 | c.1438C>T p.R480C | Missense Mutation (SNP) | VAF 199/417 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs370351341, COSV58009335; called by muse, mutect2, varscan2
- APC2 | c.2267A>G p.K756R | Missense Mutation (SNP) | VAF 25/1088 reads (2%) | SIFT deleterious (0.03); PolyPhen benign (0.132); catalogued as rs1568177709; called by muse, mutect2
- ARC | c.448G>A p.V150M | Missense Mutation (SNP) | VAF 68/1062 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); catalogued as rs922561519; called by muse, mutect2
- ARHGAP23 | c.2323G>A p.V775M | Missense Mutation (SNP) | VAF 271/575 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1300515552; called by muse, mutect2, varscan2
- ARHGAP35 | c.4204C>T p.P1402S | Missense Mutation (SNP) | VAF 230/485 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68330853; called by muse, mutect2, varscan2
- ARHGAP45 | c.2902G>A p.V968I | Missense Mutation (SNP) | VAF 276/574 reads (48%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as rs752300010; called by muse, mutect2, varscan2
- ARHGEF18 | c.568G>A p.A190T (on ENST00000359920 / NM_001130955.2; = p.A86T on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 179/412 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as rs1421608652, COSV100150046; called by muse, mutect2, varscan2
- ARHGEF37 | c.1667G>A p.R556H | Missense Mutation (SNP) | VAF 132/303 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs779590644; called by muse, varscan2
- ARHGEF7 | c.716G>A p.R239H (on ENST00000375741 / NM_001113511.2; = p.R61H on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 180/391 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs759964144, COSV54546823; called by muse, mutect2, varscan2
- ARSI | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 292/587 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs770975318; called by muse, mutect2, varscan2
- ASXL1 | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 105/215 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.069); catalogued as rs1259109293, COSV60103968; called by muse, mutect2, varscan2
- ASXL1 | c.2894G>A p.R965Q | Missense Mutation (SNP) | VAF 175/371 reads (47%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as COSV100037232; called by muse, mutect2, varscan2
- ATAD3C | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 128/273 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.335); catalogued as rs1553198590, COSV66483286; called by muse, mutect2, varscan2
- ATAT1 | c.47C>T p.T16M | Missense Mutation (SNP) | VAF 373/797 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs761639993; called by muse, mutect2, varscan2
- ATE1 | c.502C>T p.Q168* | Nonsense Mutation (SNP) | VAF 154/350 reads (44%) | catalogued as COSV99816647; called by muse, mutect2, varscan2
- ATG2A | c.5330G>A p.R1777H | Missense Mutation (SNP) | VAF 286/629 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs148815593; called by muse, mutect2, varscan2
- ATP13A1 | c.1297G>A p.G433R | Missense Mutation (SNP) | VAF 142/256 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs748074301, COSV99366716; called by muse, mutect2, varscan2
- ATP2C2 | c.2663C>T p.A888V | Missense Mutation (SNP) | VAF 206/460 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.145); catalogued as rs765192423; called by muse, varscan2
- AXIN1 | c.2240C>T p.A747V | Missense Mutation (SNP) | VAF 339/695 reads (49%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs773933232, COSV51985762; called by muse, mutect2, varscan2
- B3GAT3 | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 237/510 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs371091579; called by muse, mutect2, varscan2
- B3GNT3 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 280/569 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV100592803; called by muse, mutect2, varscan2
- BACE2 | c.305del p.P102Rfs*25 | Frame Shift Del (DEL) | VAF 152/350 reads (43%) | catalogued as rs771098505; called by mutect2, varscan2
- BARD1 | c.2161G>A p.A721T | Missense Mutation (SNP) | VAF 156/334 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as rs554708247; ClinVar: uncertain significance; called by muse, varscan2
- BCAS3 | c.2590G>A p.D864N (on ENST00000390652 / NM_001353144.2; = p.D849N on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 254/521 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs765640675; called by muse, mutect2, varscan2
- BCAT2 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 259/564 reads (46%) | SIFT tolerated (0.59); PolyPhen benign (0.023); catalogued as COSV60273709; called by muse, mutect2, varscan2
- BCL9L | c.3380del p.P1127Hfs*21 | Frame Shift Del (DEL) | VAF 314/648 reads (48%) | catalogued as rs751794665; called by mutect2, varscan2
- BFSP2 | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 265/535 reads (50%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs1020694617, COSV56589924; called by muse, mutect2, varscan2
- BICC1 | c.1351G>A p.G451R | Missense Mutation (SNP) | VAF 142/298 reads (48%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.999); catalogued as COSV99570293; called by muse, mutect2, varscan2
- BICD2 | c.1708G>T p.G570W | Missense Mutation (SNP) | VAF 36/1171 reads (3%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.884); catalogued as COSV104418004; called by muse, mutect2
- BIRC6 | c.11801G>A p.R3934H | Missense Mutation (SNP) | VAF 149/329 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs766431375, COSV70198526; called by muse, mutect2, varscan2
- BMPR2 | c.1133G>A p.G378D | Missense Mutation (SNP) | VAF 112/225 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65809663; called by muse, mutect2, varscan2
- BOK | c.222C>T p.G74= | Splice Region (SNP) | VAF 172/412 reads (42%) | catalogued as rs1435050836; called by muse, mutect2, varscan2
- BRAT1 | c.346G>A p.V116I | Missense Mutation (SNP) | VAF 380/831 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs750543404; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BSN | c.7586G>T p.R2529L | Missense Mutation (SNP) | VAF 232/561 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as rs150170628, COSV99610221; called by muse, mutect2, varscan2
- BSN | c.8521C>T p.R2841C | Missense Mutation (SNP) | VAF 315/617 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748335384, COSV56514177; called by muse, mutect2, varscan2
- BTBD6 | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 48/738 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as rs1170100270, COSV59267305; called by muse, mutect2
- BTN2A1 | c.1354G>A p.V452I | Missense Mutation (SNP) | VAF 217/440 reads (49%) | SIFT tolerated (0.84); PolyPhen benign (0.029); catalogued as rs201996542, COSV57002176; called by muse, mutect2, varscan2
- BTNL9 | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 58/956 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.11); catalogued as rs567861680; called by muse, mutect2
- C12orf40 | c.18del p.S7Pfs*6 | Frame Shift Del (DEL) | VAF 175/490 reads (36%) | catalogued as COSV61129099; called by mutect2, pindel, varscan2
- C12orf50 | c.1036G>A p.A346T | Missense Mutation (SNP) | VAF 193/429 reads (45%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs149469123, COSV100072119; called by muse, mutect2, varscan2
- C1QL2 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 29/643 reads (5%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.983); catalogued as COSV55606064; called by muse, mutect2
- C1orf35 | c.559_561del p.K187del | In Frame Del (DEL) | VAF 116/261 reads (44%) | catalogued as rs746766819; called by pindel, varscan2
- C6orf15 | c.79C>T p.R27W | Missense Mutation (SNP) | VAF 193/391 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1363195199, COSV52539636; called by muse, mutect2, varscan2
- C6orf163 | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 123/242 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1244387542, COSV100851119; called by muse, mutect2, varscan2
- CACNA1A | c.6898del p.R2300Gfs*9 | Frame Shift Del (DEL) | VAF 170/434 reads (39%) | catalogued as rs1180079360; called by pindel, varscan2
- CACNA1H | c.3553G>A p.A1185T | Missense Mutation (SNP) | VAF 430/895 reads (48%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs375742212; called by muse, mutect2, varscan2
- CACNA2D3 | c.1646G>A p.R549Q | Missense Mutation (SNP) | VAF 159/342 reads (46%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.791); catalogued as rs373496650, COSV55543373; called by muse, mutect2, varscan2
- CALN1 | c.4C>T p.P2S (on ENST00000329008 / NM_001017440.3; = p.P44S on NM_031468.4) | Missense Mutation (SNP) | VAF 115/249 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs868834341, COSV100206155; called by muse, mutect2, varscan2
- CAMSAP3 | c.571C>T p.R191* | Nonsense Mutation (SNP) | VAF 296/646 reads (46%) | catalogued as rs201421228; called by muse, mutect2, varscan2
- CAMSAP3 | c.1006del p.R336Gfs*42 | Frame Shift Del (DEL) | VAF 234/556 reads (42%) | catalogued as rs754747174; called by mutect2, pindel, varscan2
- CARD10 | c.883C>T p.R295W | Missense Mutation (SNP) | VAF 240/530 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs1215053937; called by mutect2, varscan2
- CASS4 | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 307/663 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1236494477, COSV64385645; called by muse, mutect2, varscan2
- CAV1 | c.460A>G p.T154A | Missense Mutation (SNP) | VAF 152/317 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.193); catalogued as rs779131902; called by muse, mutect2, varscan2
- CAVIN3 | c.710C>T p.P237L | Missense Mutation (SNP) | VAF 317/664 reads (48%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as COSV58270041; called by muse, mutect2, varscan2
- CBFA2T3 | c.1901C>T p.A634V | Missense Mutation (SNP) | VAF 363/764 reads (48%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); catalogued as rs144418331; called by muse, mutect2, varscan2
- CC2D2A | c.3065G>A p.R1022Q | Missense Mutation (SNP) | VAF 171/377 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.505); catalogued as rs770896540, COSV67503165; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCAR2 | c.47G>A p.R16H | Missense Mutation (SNP) | VAF 172/399 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.976); catalogued as COSV51515309; called by muse, mutect2, varscan2
- CCDC102B | c.79G>A p.G27S | Missense Mutation (SNP) | VAF 158/340 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs374892818; called by muse, mutect2, varscan2
- CCDC141 | c.2024C>T p.T675M | Missense Mutation (SNP) | VAF 187/404 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.143); catalogued as COSV55377580; called by muse, mutect2, varscan2
- CCDC148 | c.1251del p.I418* | Frame Shift Del (DEL) | VAF 74/159 reads (47%) | catalogued as rs758917400; called by mutect2, varscan2
- CCDC150 | c.1906C>T p.R636* | Nonsense Mutation (SNP) | VAF 115/238 reads (48%) | catalogued as rs1205100593; called by muse, mutect2, varscan2
- CCDC17 | c.1753G>A p.A585T | Missense Mutation (SNP) | VAF 145/289 reads (50%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs1166204426; called by muse, mutect2, varscan2
- CCDC171 | c.298C>T p.R100W | Missense Mutation (SNP) | VAF 138/313 reads (44%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.481); catalogued as rs142125441; called by muse, mutect2, varscan2
- CCDC27 | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 254/508 reads (50%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs1276108731, COSV53900510, COSV53903054; called by muse, mutect2, varscan2
- CCR7 | c.1057C>T p.R353W | Missense Mutation (SNP) | VAF 233/506 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs746812817, COSV104370453; called by muse, mutect2, varscan2
- CD163 | c.3034C>T p.R1012C | Missense Mutation (SNP) | VAF 36/374 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs752858863, COSV63129802; called by muse, mutect2
- CD163L1 | c.2042T>A p.I681N | Missense Mutation (SNP) | VAF 106/220 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.215); catalogued as COSV58026216; called by muse, mutect2, varscan2
- CDCA7L | c.710C>T p.S237L | Missense Mutation (SNP) | VAF 114/240 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs770755131; called by muse, mutect2, varscan2
- CDH7 | c.1070C>T p.P357L | Missense Mutation (SNP) | VAF 90/253 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59880968; called by muse, mutect2, varscan2
- CECR2 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 55/107 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52847961; called by muse, mutect2, varscan2
- CEL | c.2115del p.V706* (on ENST00000673714; = p.V703* on NM_001807.6) | Frame Shift Del (DEL) | VAF 96/209 reads (46%) | catalogued as rs768251399; called by mutect2, varscan2
- CELSR3 | c.3857G>A p.R1286H | Missense Mutation (SNP) | VAF 331/588 reads (56%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as COSV99375431; called by muse, mutect2, varscan2
- CEP63 | c.1088C>T p.T363M | Missense Mutation (SNP) | VAF 114/244 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.975); catalogued as rs376104307; called by muse, mutect2, varscan2
- CFAP43 | c.641del p.F214Sfs*24 | Frame Shift Del (DEL) | VAF 116/326 reads (36%) | catalogued as rs1200626661; called by pindel, varscan2
- CFAP58 | c.1429del p.I477* | Frame Shift Del (DEL) | VAF 74/228 reads (32%) | catalogued as rs761844995; called by pindel, varscan2
- CHD7 | c.1610G>A p.W537* | Nonsense Mutation (SNP) | VAF 202/500 reads (40%) | catalogued as CM080143, COSV101418170; called by muse, mutect2, varscan2
- CHD8 | c.5684G>A p.R1895H (on ENST00000646647 / NM_001170629.2; = p.R1616H on NM_020920.4) | Missense Mutation (SNP) | VAF 147/307 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs1408226614; called by muse, mutect2, varscan2
- CHGA | c.1214C>T p.A405V | Missense Mutation (SNP) | VAF 255/507 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.293); catalogued as rs1305910970; called by muse, mutect2, varscan2
- CHPF | c.1432C>T p.R478C | Missense Mutation (SNP) | VAF 287/602 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs200725116; called by muse, mutect2, varscan2
- CHRM4 | c.1186C>T p.R396C | Missense Mutation (SNP) | VAF 273/329 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs769639848; called by muse, mutect2, varscan2
- CHRNA2 | c.1253A>T p.E418V | Missense Mutation (SNP) | VAF 324/669 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1453727330, COSV53556180; called by muse, mutect2, varscan2
- CHRNE | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 144/329 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as rs773435892; called by muse, mutect2, varscan2
- CHST3 | c.1214C>T p.T405M | Missense Mutation (SNP) | VAF 50/644 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV64151482; called by muse, mutect2
- CHTF18 | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 178/410 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772811355; called by muse, mutect2
- CKAP2 | c.1817del p.K606Rfs*14 (on ENST00000378037 / NM_001098525.2; = p.K605Rfs*14 on NM_018204.5) | Frame Shift Del (DEL) | VAF 58/122 reads (48%) | catalogued as rs752250702; called by mutect2, varscan2
- CLASP2 | c.3713G>A p.R1238Q (on ENST00000359576; = p.R1237Q on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 111/241 reads (46%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as rs778905362; called by muse, mutect2, varscan2
- CLCN5 | c.1892T>C p.L631P | Missense Mutation (SNP) | VAF 128/128 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as rs782795970; called by muse, mutect2, varscan2
- CNBD1 | c.399A>T p.K133N | Missense Mutation (SNP) | VAF 132/228 reads (58%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV72917598; called by muse, mutect2, varscan2
- CNTNAP4 | c.380A>G p.D127G | Missense Mutation (SNP) | VAF 84/201 reads (42%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.808); catalogued as rs139740249, COSV100269291; called by muse, mutect2, varscan2
- CNTNAP4 | c.1924A>C p.T642P | Missense Mutation (SNP) | VAF 134/264 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.397); catalogued as COSV56666867; called by muse, mutect2, varscan2
- CNTNAP5 | c.874T>G p.F292V | Missense Mutation (SNP) | VAF 229/453 reads (51%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.998); catalogued as COSV70488253; called by mutect2, varscan2
- COBL | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 115/207 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs149682754; called by muse, mutect2, varscan2
- COL26A1 | c.367G>A p.G123R (on ENST00000313669 / NM_001278563.3; = p.G121R on NM_133457.4) | Missense Mutation (SNP) | VAF 153/358 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367929550, COSV100561912; called by muse, mutect2, varscan2
- COL4A3 | c.1459G>A p.G487S | Missense Mutation (SNP) | VAF 154/304 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs745472969, CM072958, COSV67412847; called by muse, mutect2, varscan2
- COL5A1 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 128/292 reads (44%) | SIFT tolerated (0.75); PolyPhen benign (0.015); catalogued as rs761079177, COSV65667285; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- COL5A2 | c.4325G>A p.R1442Q | Missense Mutation (SNP) | VAF 96/208 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.908); catalogued as rs761126767, COSV66414520; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A3 | c.1006C>T p.R336W | Missense Mutation (SNP) | VAF 44/751 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as rs200720222, COSV99797818; ClinVar: uncertain significance; called by muse, mutect2
- CPNE1 | c.136C>T p.R46W (on ENST00000352393; = p.R51W on NM_003915.5) | Missense Mutation (SNP) | VAF 96/216 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1329217194, COSV58293159; called by muse, varscan2
- CPSF3 | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 188/411 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as rs1449023124, COSV53009379; called by muse, mutect2, varscan2
- CRACDL | c.1170G>T p.E390D | Missense Mutation (SNP) | VAF 72/1051 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.366); catalogued as COSV67409629; called by muse, mutect2
- CRAT | c.1769C>T p.S590L | Missense Mutation (SNP) | VAF 247/522 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs767998416, COSV58877168; called by muse, mutect2, varscan2
- CREBBP | c.6071C>T p.A2024V | Missense Mutation (SNP) | VAF 381/775 reads (49%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as rs745551441, CD065690; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CROT | c.102del p.K34Nfs*6 | Frame Shift Del (DEL) | VAF 92/210 reads (44%) | catalogued as rs756999481; called by mutect2, pindel, varscan2
- CRYBB1 | c.488C>T p.T163I | Missense Mutation (SNP) | VAF 182/471 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); catalogued as rs775834856; called by muse, mutect2, varscan2
- CRYGS | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 141/281 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as rs747787300, COSV57192779; called by muse, mutect2, varscan2
- CSMD2 | c.5347G>T p.A1783S | Missense Mutation (SNP) | VAF 244/490 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53911192; called by muse, mutect2, varscan2
- CTAGE4 | c.2168del p.P723Hfs*30 | Frame Shift Del (DEL) | VAF 224/1061 reads (21%) | catalogued as rs1237225733; called by mutect2, pindel, varscan2
- CTC1 | c.1363C>T p.Q455* | Nonsense Mutation (SNP) | VAF 259/546 reads (47%) | catalogued as COSV100236707; called by muse, mutect2, varscan2
- CTDSPL2 | c.125C>T p.S42L | Missense Mutation (SNP) | VAF 280/444 reads (63%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.003); catalogued as rs200841761; called by muse, mutect2
- CTTNBP2NL | c.1387C>T p.R463C | Missense Mutation (SNP) | VAF 220/425 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1192829350, COSV99078226; called by muse, mutect2, varscan2
- CUX2 | c.3551G>A p.R1184Q | Missense Mutation (SNP) | VAF 338/681 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs747760741, COSV55644054; called by muse, mutect2, varscan2
- CWF19L2 | c.287del p.K96Rfs*41 | Frame Shift Del (DEL) | VAF 46/130 reads (35%) | catalogued as rs772257590; called by mutect2, varscan2
- CXCR4 | c.415G>A p.V139I | Missense Mutation (SNP) | VAF 200/390 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs1451071577, COSV99602554; called by muse, mutect2, varscan2
- CYP2A13 | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 180/422 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs753627766, COSV100386989; called by muse, varscan2
- CYP2D6 | c.1490G>A p.R497H | Missense Mutation (SNP) | VAF 177/425 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1440526469; called by muse, mutect2, varscan2
- CYP4F3 | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 134/344 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs759750064, COSV55414262; called by muse, mutect2, varscan2
- CYP51A1 | c.1271G>A p.R424H | Missense Mutation (SNP) | VAF 127/273 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.389); catalogued as rs746098957, COSV50151688; called by muse, mutect2, varscan2
- CYRIA | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 133/277 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.627); catalogued as rs868184603, COSV62865285, COSV62865408; called by muse, mutect2, varscan2
- CYSLTR2 | c.805G>A p.V269I | Missense Mutation (SNP) | VAF 175/384 reads (46%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs777488065, COSV56165082; called by muse, mutect2, varscan2
- DAB2IP | c.1237C>T p.R413W (on ENST00000408936; = p.R385W on NM_032552.3) | Missense Mutation (SNP) | VAF 230/506 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370747909; called by muse, varscan2
- DBNL | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 285/604 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.468); catalogued as rs752137757; called by muse, mutect2, varscan2
- DCP2 | c.521T>C p.L174S | Missense Mutation (SNP) | VAF 126/342 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1197659283; called by muse, mutect2, varscan2
- DCTN1 | c.1102G>A p.A368T | Missense Mutation (SNP) | VAF 88/211 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.378); catalogued as rs1034996844, COSV62621376; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DDI1 | c.22G>A p.V8M | Missense Mutation (SNP) | VAF 94/380 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); catalogued as rs1288574029, COSV56368807; called by muse, mutect2, varscan2
- DDX21 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 100/236 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.727); catalogued as rs762463734; called by muse, mutect2, varscan2
- DES | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 156/309 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1475674849, COSV64660914; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DFFB | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 312/605 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100138760; called by muse, mutect2, varscan2
- DGKI | c.2767G>A p.V923I | Missense Mutation (SNP) | VAF 60/149 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs372637031; called by muse, mutect2, varscan2
- DHX34 | c.1621C>T p.R541* | Nonsense Mutation (SNP) | VAF 155/384 reads (40%) | catalogued as rs770850909; called by muse, mutect2, varscan2
- DIP2C | c.4348C>T p.R1450W | Missense Mutation (SNP) | VAF 26/482 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371430787; called by muse, mutect2
- DIPK1B | c.766C>A p.L256M | Missense Mutation (SNP) | VAF 400/861 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.109); catalogued as COSV63038312; called by muse, mutect2, varscan2
- DLC1 | c.1849del p.R617Gfs*37 (on ENST00000276297 / NM_001348081.2; = p.R180Gfs*37 on NM_006094.5) | Frame Shift Del (DEL) | VAF 389/891 reads (44%) | catalogued as COSV52307798; called by mutect2, pindel, varscan2
- DNAAF1 | c.503A>C p.N168T | Missense Mutation (SNP) | VAF 179/350 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV57576557; called by muse, varscan2
- DNAH17 | c.1955G>A p.C652Y | Missense Mutation (SNP) | VAF 266/559 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as rs371402937; called by muse, mutect2, varscan2
- DNAH17 | c.1346G>A p.R449H | Missense Mutation (SNP) | VAF 203/448 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.579); catalogued as rs748524638, COSV67759443; called by muse, mutect2, varscan2
- DNAH3 | c.8210C>T p.A2737V | Missense Mutation (SNP) | VAF 177/392 reads (45%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.993); catalogued as rs201699403; called by muse, mutect2, varscan2
- DNAJC13 | c.5200G>A p.A1734T | Missense Mutation (SNP) | VAF 180/380 reads (47%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs538703638, COSV99607004; called by muse, mutect2, varscan2
- DNAJC7 | c.610C>T p.R204* | Nonsense Mutation (SNP) | VAF 10/246 reads (4%) | catalogued as COSV57269112; called by muse, mutect2
- DNAJC7 | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 85/201 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.135); catalogued as rs1555647571; called by muse, mutect2, varscan2
- DNMBP | c.2627C>T p.A876V | Missense Mutation (SNP) | VAF 18/408 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV60634552; called by muse, mutect2
- DOC2B | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 365/735 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs759735295, COSV59096035; called by muse, mutect2, varscan2
- DPAGT1 | c.698del p.F233Sfs*28 | Frame Shift Del (DEL) | VAF 119/258 reads (46%) | catalogued as rs35482889; called by mutect2, varscan2
- DPP6 | c.1997G>C p.G666A (on ENST00000377770 / NM_001364500.2; = p.G604A on NM_001936.5) | Missense Mutation (SNP) | VAF 404/838 reads (48%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV59599615; called by muse, mutect2
- DPPA2 | c.289C>T p.R97W | Missense Mutation (SNP) | VAF 160/343 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.076); catalogued as rs759064635, COSV101524802, COSV72117956; called by muse, mutect2, varscan2
- DRC7 | c.1781G>A p.R594H | Missense Mutation (SNP) | VAF 165/370 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as rs1279392609, COSV61054025; called by muse, mutect2, varscan2
- DRD1 | c.1181C>T p.A394V | Missense Mutation (SNP) | VAF 153/308 reads (50%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV67105122, COSV67105179; called by muse, mutect2, varscan2
- DROSHA | c.2333G>A p.R778H | Missense Mutation (SNP) | VAF 87/185 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); catalogued as COSV60773848; called by muse, mutect2, varscan2
- DSG1 | c.550G>A p.A184T | Missense Mutation (SNP) | VAF 89/202 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757446872, COSV57138717; called by muse, mutect2, varscan2
- DSG1 | c.691G>A p.G231S | Missense Mutation (SNP) | VAF 117/291 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs535358304; called by muse, mutect2, varscan2
- DTHD1 | c.164del p.N55Ifs*5 (on ENST00000456874; = p.N180Ifs*5 on NM_001170700.3) | Frame Shift Del (DEL) | VAF 106/263 reads (40%) | catalogued as rs34134908; called by mutect2, pindel, varscan2
- DUOX1 | c.2921G>A p.R974H | Missense Mutation (SNP) | VAF 88/454 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs552301388; called by muse, varscan2
- DUOX1 | c.4568del p.P1523Lfs*3 | Frame Shift Del (DEL) | VAF 427/854 reads (50%) | catalogued as rs751561010; called by mutect2, pindel, varscan2
- DVL3 | c.136_138del p.F46del | In Frame Del (DEL) | VAF 198/435 reads (46%) | catalogued as rs748722318; called by pindel, varscan2
- DVL3 | c.1979del p.P660Lfs*8 | Frame Shift Del (DEL) | VAF 337/725 reads (46%) | catalogued as COSV53047877; called by mutect2, pindel, varscan2
- DZIP3 | c.1204_1206del p.I402del | In Frame Del (DEL) | VAF 78/196 reads (40%) | catalogued as rs1241059554; called by pindel, varscan2
- E2F2 | c.1253C>T p.A418V | Missense Mutation (SNP) | VAF 203/409 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs368795371; called by muse, mutect2, varscan2
- EEF1A2 | c.776T>C p.I259T | Missense Mutation (SNP) | VAF 184/395 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53207002; called by muse, mutect2, varscan2
- EFCAB5 | c.3266_3268del p.F1089del | In Frame Del (DEL) | VAF 121/282 reads (43%) | catalogued as rs1160128978; called by pindel, varscan2
- ELANE | c.301G>A p.V101M | Missense Mutation (SNP) | VAF 422/842 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as rs137854449, CM002594, COSV55049496; called by muse, varscan2
- EMILIN2 | c.3014C>T p.P1005L | Missense Mutation (SNP) | VAF 306/643 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs201007246; called by muse, mutect2, varscan2
- ENDOU | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 194/436 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.058); catalogued as rs776957197; called by muse, mutect2, varscan2
- ENO4 | c.1688G>A p.R563H (on ENST00000622726; = p.R560H on NM_001242699.2) | Missense Mutation (SNP) | VAF 129/302 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1185737561, COSV99598545; called by muse, mutect2, varscan2
- EP300 | c.5266C>T p.P1756S | Missense Mutation (SNP) | VAF 228/455 reads (50%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.763); catalogued as rs1358517771; called by muse, mutect2, varscan2
- EPB41 | c.1670G>A p.R557Q (on ENST00000343067 / NM_001166005.2; = p.R348Q on NM_004437.4) | Missense Mutation (SNP) | VAF 161/368 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.63); catalogued as rs201952060; called by muse, mutect2, varscan2
- EPHA3 | c.2921C>T p.T974M | Missense Mutation (SNP) | VAF 163/334 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as rs780470195, COSV60693883, COSV60732575; called by muse, mutect2, varscan2
- EPHB1 | c.2524C>T p.R842W | Missense Mutation (SNP) | VAF 203/401 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67674342; called by muse, mutect2, varscan2
- ERF | c.896del p.G299Efs*12 | Frame Shift Del (DEL) | VAF 295/789 reads (37%) | catalogued as rs780487406; called by mutect2, pindel, varscan2
- ERICH3 | c.3385G>A p.E1129K | Missense Mutation (SNP) | VAF 202/401 reads (50%) | SIFT tolerated (0.4); PolyPhen benign (0.209); catalogued as rs866558257, COSV58599808; called by muse, mutect2, varscan2
- ERLIN2 | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 168/362 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.871); catalogued as rs372480451, COSV52421821; called by muse, mutect2, varscan2
- ERMP1 | c.1951del p.T651Pfs*3 | Frame Shift Del (DEL) | VAF 100/252 reads (40%) | catalogued as rs753821453; called by mutect2, varscan2
- ERN2 | c.2438C>T p.A813V | Missense Mutation (SNP) | VAF 301/611 reads (49%) | SIFT tolerated (0.27); PolyPhen benign (0.108); catalogued as rs753152091, COSV99892647; called by muse, mutect2, varscan2
- ERVMER34-1 | c.899del p.L300Cfs*33 | Frame Shift Del (DEL) | VAF 148/308 reads (48%) | catalogued as rs779855268; called by mutect2, varscan2
- ETS1 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 194/402 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs763167051, COSV60093421, COSV60093906; called by muse, varscan2
- EVI2B | c.593del p.N198Tfs*6 | Frame Shift Del (DEL) | VAF 238/342 reads (70%) | catalogued as rs765136869; called by mutect2, pindel, varscan2
- FAM135B | c.3925G>A p.V1309M | Missense Mutation (SNP) | VAF 130/292 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52724376; called by muse, mutect2, varscan2
- FAM193B | c.219dup p.A74Rfs*34 | Frame Shift Ins (INS) | VAF 138/297 reads (46%) | catalogued as rs765995572; called by mutect2, varscan2
- FAM20A | c.755_757del p.F252del | In Frame Del (DEL) | VAF 104/212 reads (49%) | catalogued as rs768121766; called by pindel, varscan2
- FAM71C | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 174/395 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.036); catalogued as rs751298344, COSV60944504; called by muse, mutect2, varscan2
- FAM83G | c.1957dup p.H653Pfs*57 | Frame Shift Ins (INS) | VAF 248/647 reads (38%) | catalogued as rs768167872; called by mutect2, pindel, varscan2
- FAM83H | c.1043G>A p.R348H | Missense Mutation (SNP) | VAF 294/600 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1350463425; called by muse, varscan2
- FAM83H | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 381/810 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781869580; called by muse, mutect2, varscan2
- FASLG | c.422del p.K141Rfs*3 | Frame Shift Del (DEL) | VAF 104/216 reads (48%) | catalogued as rs35774809; called by mutect2, varscan2
- FBLN1 | c.1982G>A p.R661H | Missense Mutation (SNP) | VAF 26/496 reads (5%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.557); catalogued as rs369461467; called by muse, mutect2
- FBN3 | c.7160G>A p.R2387H | Missense Mutation (SNP) | VAF 234/494 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs777095907, COSV99560822; called by muse, mutect2, varscan2
- FBRSL1 | c.876del p.A293Pfs*121 | Frame Shift Del (DEL) | VAF 340/817 reads (42%) | catalogued as rs1461432773; called by mutect2, pindel, varscan2
- FBXL20 | c.1054G>A p.A352T | Missense Mutation (SNP) | VAF 29/522 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.734); catalogued as COSV52904551; called by muse, mutect2
- FBXL22 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 322/983 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.923); catalogued as rs531949187; called by muse, mutect2, varscan2
- FERMT2 | c.168del p.D57Ifs*17 | Frame Shift Del (DEL) | VAF 86/182 reads (47%) | catalogued as rs1225761410; called by mutect2, varscan2
- FERMT3 | c.337C>T p.R113C | Missense Mutation (SNP) | VAF 404/799 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs757621690, COSV54184072; called by muse, mutect2, varscan2
- FES | c.979C>T p.R327W | Missense Mutation (SNP) | VAF 269/410 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs199975821; called by muse, mutect2, varscan2
- FGF11 | c.614T>C p.M205T | Missense Mutation (SNP) | VAF 162/338 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs762753911; called by muse, mutect2, varscan2
- FGFR4 | c.2108G>A p.R703Q | Missense Mutation (SNP) | VAF 327/695 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.738); catalogued as rs759521008; called by muse, mutect2, varscan2
- FGGY | c.1077C>A p.C359* | Nonsense Mutation (SNP) | VAF 84/195 reads (43%) | catalogued as COSV100365934; called by muse, mutect2, varscan2
- FHIT | c.103+1G>A p.X35_splice | Splice Site (SNP) | VAF 92/226 reads (41%) | catalogued as rs768812859, COSV104421355, COSV59290351; called by muse, varscan2
- FHOD3 | c.1036G>A p.V346M | Missense Mutation (SNP) | VAF 248/527 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as rs146957872, COSV57187669; called by muse, varscan2
- FIGN | c.799dup p.A267Gfs*100 | Frame Shift Ins (INS) | VAF 208/497 reads (42%) | catalogued as rs755527396; called by mutect2, varscan2
- FKBP8 | c.605C>T p.T202M (on ENST00000222308 / NM_001308373.2; = p.T203M on NM_012181.5) | Missense Mutation (SNP) | VAF 249/580 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.227); catalogued as rs201710065, COSV55892188; called by muse, mutect2, varscan2
- FLG | c.2344C>T p.R782W | Missense Mutation (SNP) | VAF 231/486 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as rs558836936, COSV64238446, COSV64241098; called by muse, mutect2
- FLT4 | c.302T>C p.V101A | Missense Mutation (SNP) | VAF 52/799 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1330216305; called by muse, mutect2
- FMN2 | c.5047C>T p.L1683F | Missense Mutation (SNP) | VAF 62/158 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV60425942; called by muse, mutect2, varscan2
- FOCAD | c.1582C>T p.R528* | Nonsense Mutation (SNP) | VAF 107/259 reads (41%) | catalogued as rs141620768; called by muse, mutect2, varscan2
- FOXK2 | c.1240G>A p.A414T | Missense Mutation (SNP) | VAF 50/766 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.581); catalogued as rs1037736759; called by muse, mutect2
- FRAS1 | c.7721C>T p.T2574M | Missense Mutation (SNP) | VAF 46/413 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as rs552595905; called by muse, mutect2, varscan2
- FRMD4A | c.2267C>T p.S756L | Missense Mutation (SNP) | VAF 264/643 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.061); catalogued as rs749376126; called by muse, mutect2, varscan2
- FRMPD2 | c.2306C>T p.P769L | Missense Mutation (SNP) | VAF 96/250 reads (38%) | SIFT tolerated (0.75); PolyPhen benign (0.015); catalogued as rs200435407, COSV100563933, COSV59714868; called by muse, mutect2, varscan2
- FSD2 | c.1627C>T p.R543* | Nonsense Mutation (SNP) | VAF 197/760 reads (26%) | catalogued as rs1235826219, COSV58008840; called by muse, mutect2, varscan2
- FSHR | c.847C>T p.R283W | Missense Mutation (SNP) | VAF 110/258 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs200328782; called by muse, mutect2, varscan2
- FXR1 | c.544A>G p.N182D | Missense Mutation (SNP) | VAF 168/337 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs750371062; called by muse, mutect2, varscan2
- FXR2 | c.764G>A p.R255Q | Missense Mutation (SNP) | VAF 196/436 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51519493; called by muse, mutect2, varscan2
- FYB2 | c.1153dup p.M385Nfs*8 | Frame Shift Ins (INS) | VAF 68/172 reads (40%) | catalogued as rs762431846; called by mutect2, varscan2
- FYCO1 | c.2398C>T p.R800W | Missense Mutation (SNP) | VAF 293/590 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs200646936, COSV99945422; called by muse, mutect2, varscan2
- FZD10 | c.1207G>A p.A403T | Missense Mutation (SNP) | VAF 248/616 reads (40%) | SIFT tolerated (0.45); PolyPhen benign (0.038); catalogued as rs1566096589; called by muse, mutect2, varscan2
- FZD6 | c.1521del p.F507Lfs*25 | Frame Shift Del (DEL) | VAF 141/352 reads (40%) | catalogued as COSV62470622; called by mutect2, pindel, varscan2
- GABRB3 | c.773C>T p.T258M | Missense Mutation (SNP) | VAF 261/462 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100161964, COSV54652552, COSV54658230; called by muse, mutect2, varscan2
- GABRR3 | c.379A>G p.K127E | Missense Mutation (SNP) | VAF 145/309 reads (47%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.515); catalogued as COSV72084445; called by muse, mutect2, varscan2
- GALNT17 | c.128G>T p.R43L | Missense Mutation (SNP) | VAF 371/724 reads (51%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as COSV100357180; called by muse, mutect2, varscan2
- GAS7 | c.755C>T p.A252V (on ENST00000432992 / NM_201433.2; = p.A112V on NM_003644.3) | Missense Mutation (SNP) | VAF 66/273 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs765522796, COSV60445575; called by muse, mutect2, varscan2
- GCC1 | c.2209C>A p.L737M | Missense Mutation (SNP) | VAF 171/366 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.897); catalogued as COSV58461716, COSV58463071; called by muse, mutect2, varscan2
- GCSAM | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 26/320 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs371130266; called by muse, mutect2
- GIMAP1 | c.898G>A p.V300I | Missense Mutation (SNP) | VAF 277/513 reads (54%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.005); catalogued as rs752300708, COSV56188181; called by muse, mutect2, varscan2
- GIMAP8 | c.1766G>A p.R589H | Missense Mutation (SNP) | VAF 188/357 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.224); catalogued as rs1423611628, COSV56230049; called by muse, mutect2, varscan2
- GJA9 | c.688A>T p.I230F | Missense Mutation (SNP) | VAF 80/180 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1319128275; called by muse, mutect2, varscan2
- GLT6D1 | c.437G>A p.G146D | Missense Mutation (SNP) | VAF 210/438 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.146); catalogued as rs960150461, COSV65627129; called by muse, varscan2
- GNG12 | c.202dup p.T68Nfs*9 | Frame Shift Ins (INS) | VAF 70/148 reads (47%) | catalogued as rs1022402829; called by mutect2, varscan2
- GPC6 | c.1281C>A p.S427R | Missense Mutation (SNP) | VAF 95/256 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.18); catalogued as rs1179528802, COSV100988923; called by muse, mutect2, varscan2
- GPER1 | c.433G>A p.V145I | Missense Mutation (SNP) | VAF 275/671 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs776489649, COSV52469112; called by muse, mutect2, varscan2
- GPR142 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 134/304 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.435); catalogued as COSV59520361, COSV59520705; called by muse, varscan2
- GRAMD1B | c.1443C>G p.I481M | Missense Mutation (SNP) | VAF 245/488 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.122); catalogued as COSV100454894; called by muse, mutect2, varscan2
- GRID2 | c.2558C>T p.T853M | Missense Mutation (SNP) | VAF 115/284 reads (40%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.579); catalogued as rs755122604, COSV56170780; called by muse, mutect2, varscan2
- GRIK2 | c.2546del p.N849Tfs*14 | Frame Shift Del (DEL) | VAF 86/194 reads (44%) | catalogued as rs760757380; called by mutect2, varscan2
- GRIN3B | c.2804G>A p.R935H | Missense Mutation (SNP) | VAF 373/928 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1287022184; called by muse, varscan2
- GRM6 | c.1752del p.W585Gfs*128 | Frame Shift Del (DEL) | VAF 350/840 reads (42%) | catalogued as rs748223277; called by mutect2, pindel, varscan2
- GRM6 | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 60/731 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.668); catalogued as rs1386926233, COSV51446518; called by muse, mutect2
- GSX2 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 460/942 reads (49%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs1462626534; called by muse, mutect2, varscan2
- GTF2H1 | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 175/346 reads (51%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs199943432; called by muse, mutect2, varscan2
- GTF3C1 | c.4307C>T p.T1436M | Missense Mutation (SNP) | VAF 184/387 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752880004; called by muse, mutect2, varscan2
- HAGH | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 329/667 reads (49%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.911); catalogued as rs750295513; called by muse, mutect2, varscan2
- HAPLN2 | c.120dup p.I41Hfs*155 | Frame Shift Ins (INS) | VAF 236/504 reads (47%) | catalogued as rs1395882541; called by mutect2, varscan2
- HFM1 | c.4200del p.F1400Lfs*25 | Frame Shift Del (DEL) | VAF 58/163 reads (36%) | catalogued as rs766204131; called by mutect2, pindel, varscan2
- HIVEP3 | c.5285G>A p.R1762H | Missense Mutation (SNP) | VAF 236/476 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1403670515, COSV56012853; called by muse, varscan2
- HPD | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 74/387 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.288); catalogued as rs753729361; called by muse, mutect2, varscan2
- HS3ST6 | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 305/810 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.023); catalogued as rs760978161; called by muse, varscan2
- HUWE1 | c.9694C>T p.R3232C | Missense Mutation (SNP) | VAF 227/227 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53334525; called by muse, mutect2, varscan2
- IDH1 | c.638del p.N213Tfs*4 | Frame Shift Del (DEL) | VAF 169/377 reads (45%) | catalogued as COSV61628152; called by mutect2, pindel, varscan2
- IFFO1 | c.1089del p.R364Gfs*47 (on ENST00000396840 / NM_001330324.2; = p.R367Gfs*47 on NM_080730.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 237/641 reads (37%) | catalogued as rs750779916, COSV60737300; called by mutect2, pindel, varscan2
- IFT122 | c.3536G>A p.R1179Q (on ENST00000348417 / NM_052989.3; = p.R1120Q on NM_018262.4) | Missense Mutation (SNP) | VAF 289/598 reads (48%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.978); catalogued as rs766429633; called by muse, mutect2, varscan2
- IGF1R | c.3616G>A p.A1206T | Missense Mutation (SNP) | VAF 102/642 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.389); catalogued as rs772355972, COSV51269233; called by muse, mutect2, varscan2
- IGSF5 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 151/330 reads (46%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as rs768818137, COSV66031386; called by muse, mutect2, varscan2
- IL22RA2 | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 163/352 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377248470, COSV51663463; called by muse, mutect2, varscan2
- ILK | c.1001G>A p.R334Q | Missense Mutation (SNP) | VAF 119/282 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs566678782, COSV54989672; called by muse, mutect2, varscan2
- INO80B | c.767dup p.A257Rfs*75 | Frame Shift Ins (INS) | VAF 190/478 reads (40%) | catalogued as rs761589557; called by mutect2, varscan2
- INO80D | c.2569G>A p.A857T | Missense Mutation (SNP) | VAF 171/364 reads (47%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.269); catalogued as rs760035543, COSV68959225; called by muse, mutect2, varscan2
- IPO5 | c.1589A>G p.Y530C | Missense Mutation (SNP) | VAF 173/334 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs777237462; called by muse, mutect2, varscan2
- IQGAP1 | c.1189G>A p.A397T | Missense Mutation (SNP) | VAF 248/408 reads (61%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs757305867; called by muse, mutect2, varscan2
- IRAK1 | c.683G>A p.R228Q | Missense Mutation (SNP) | VAF 312/312 reads (100%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.742); catalogued as rs1557130303; called by muse, mutect2, varscan2
- IRGQ | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 312/653 reads (48%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.744); catalogued as COSV60670227; called by muse, mutect2, varscan2
- IRS4 | c.1250C>T p.P417L | Missense Mutation (SNP) | VAF 373/373 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs143848880; called by muse, mutect2, varscan2
- IRX1 | c.1166G>A p.R389H | Missense Mutation (SNP) | VAF 57/901 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57358038; called by muse, mutect2
- ITSN2 | c.4189C>T p.R1397W | Missense Mutation (SNP) | VAF 294/577 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759015898; called by muse, mutect2, varscan2
- IVL | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 132/313 reads (42%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.833); catalogued as rs776300444; called by muse, mutect2, varscan2
- JAG2 | c.1390G>A p.D464N | Missense Mutation (SNP) | VAF 331/650 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.616); catalogued as rs748437262, COSV59308704; called by muse, mutect2, varscan2
- JPH1 | c.1475C>T p.A492V | Missense Mutation (SNP) | VAF 197/416 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs377278223; called by muse, mutect2, varscan2
- KATNAL2 | c.1166G>A p.R389H (on ENST00000356157 / NM_001353899.1; = p.R317H on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 153/330 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.117); catalogued as rs566442595; called by muse, mutect2, varscan2
- KATNIP | c.1552C>T p.R518W | Missense Mutation (SNP) | VAF 221/456 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs201676999; called by muse, mutect2, varscan2
- KCNQ3 | c.1306C>T p.R436C | Missense Mutation (SNP) | VAF 118/258 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs895278799, COSV101195619, COSV66478081; called by muse, mutect2, varscan2
- KDM2B | c.3871C>T p.R1291C | Missense Mutation (SNP) | VAF 225/495 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs782308648, COSV100997461; called by muse, mutect2, varscan2
- KDM2B | c.872G>A p.R291H | Missense Mutation (SNP) | VAF 213/460 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); catalogued as rs534727815; called by muse, mutect2, varscan2
- KIAA1549 | c.2317G>A p.G773S | Missense Mutation (SNP) | VAF 198/437 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs779721937; called by muse, mutect2, varscan2
- KIAA1671 | c.1060C>T p.R354W | Missense Mutation (SNP) | VAF 239/461 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.409); catalogued as rs1038463756; called by muse, mutect2, varscan2
- KIAA1755 | c.3479G>A p.R1160Q | Missense Mutation (SNP) | VAF 329/652 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.038); catalogued as rs765394645; called by muse, mutect2, varscan2
- KIF24 | c.823del p.Y275Ifs*17 | Frame Shift Del (DEL) | VAF 100/255 reads (39%) | catalogued as rs1245234575; called by mutect2, pindel, varscan2
- KIF26A | c.4556C>T p.T1519M | Missense Mutation (SNP) | VAF 474/970 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs552359730, COSV59466307; called by muse, mutect2
- KLC4 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 233/467 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as rs777889139; called by muse, mutect2, varscan2
- KLC4 | c.1653G>T p.R551S | Missense Mutation (SNP) | VAF 143/280 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as COSV52435261; called by muse, mutect2, varscan2
- KLHL18 | c.569G>A p.R190Q | Missense Mutation (SNP) | VAF 108/212 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.041); catalogued as rs780179955, COSV99230520; called by muse, varscan2
- KLHL34 | c.1855G>A p.A619T | Missense Mutation (SNP) | VAF 324/376 reads (86%) | SIFT tolerated (0.18); PolyPhen benign (0.106); catalogued as COSV101069884; called by muse, varscan2
- KLHL34 | c.1823C>T p.A608V | Missense Mutation (SNP) | VAF 221/399 reads (55%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV101070005; called by muse, varscan2
- KLHL9 | c.1219C>T p.R407C | Missense Mutation (SNP) | VAF 167/347 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62921748; called by muse, mutect2, varscan2
- KLK8 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 207/419 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs771795082, COSV51591962; called by muse, mutect2, varscan2
- KNDC1 | c.2663C>T p.T888M | Missense Mutation (SNP) | VAF 296/619 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as rs778443990; called by muse, mutect2, varscan2
- KRT10 | c.1648G>A p.G550S | Missense Mutation (SNP) | VAF 436/828 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs1176342005; called by muse, varscan2
- KRT27 | c.810G>T p.Q270H | Missense Mutation (SNP) | VAF 227/509 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV56972990; called by muse, mutect2, varscan2
- LARP1B | c.2361del p.K787Nfs*26 | Frame Shift Del (DEL) | VAF 115/242 reads (48%) | catalogued as rs758463950; called by mutect2, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 89/235 reads (38%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LARS1 | c.1862C>A p.S621Y (on ENST00000394434 / NM_020117.11; = p.S594Y on NM_016460.3) | Missense Mutation (SNP) | VAF 122/277 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as COSV99199042; called by muse, mutect2, varscan2
- LBX1 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 268/520 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64621476; called by muse, varscan2
- LCE1A | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 294/584 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1243330178, COSV58726648; called by muse, mutect2, varscan2
- LCE2C | c.253C>T p.R85W | Missense Mutation (SNP) | VAF 332/702 reads (47%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.895); catalogued as rs777666120, COSV64228433; called by muse, mutect2, varscan2
- LEMD1 | c.182C>T p.A61V | Missense Mutation (SNP) | VAF 175/355 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs774547030, COSV65671111; called by muse, mutect2, varscan2
- LILRB5 | c.491G>T p.R164M | Missense Mutation (SNP) | VAF 290/642 reads (45%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.887); catalogued as COSV60257047; called by muse, mutect2, varscan2
- LIMK1 | c.601G>A p.V201I | Missense Mutation (SNP) | VAF 232/462 reads (50%) | SIFT tolerated (0.31); PolyPhen benign (0.29); catalogued as rs782691662, COSV100283528; called by muse, mutect2, varscan2
- LIN28B | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 217/439 reads (49%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as rs769136643, COSV61493023; called by muse, mutect2, varscan2
- LIPC | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 587/978 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs766415805; called by muse, varscan2
- LONP1 | c.2752_2754del p.K918del | In Frame Del (DEL) | VAF 233/480 reads (49%) | catalogued as rs751060700; called by pindel, varscan2
- LOXL2 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 264/570 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1440188157, COSV66691974; called by muse, mutect2, varscan2
- LPA | c.2603C>T p.A868V | Missense Mutation (SNP) | VAF 108/365 reads (30%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.935); catalogued as rs757112211, COSV60295974; called by muse, mutect2, varscan2
- LPAR4 | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 217/217 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1279273307; called by muse, mutect2, varscan2
- LRATD2 | c.887dup p.A297Cfs*113 | Frame Shift Ins (INS) | VAF 190/747 reads (25%) | catalogued as rs757617035; called by mutect2, pindel, varscan2
- LRIT1 | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 151/298 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64512148; called by muse, mutect2, varscan2
- LRP10 | c.1784G>T p.G595V | Missense Mutation (SNP) | VAF 416/842 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100612264; called by muse, mutect2, varscan2
- LRP1B | c.1693G>A p.A565T | Missense Mutation (SNP) | VAF 111/242 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.207); catalogued as rs759283974, COSV67203627; called by muse, mutect2, varscan2
- LRP2 | c.11809A>G p.N3937D | Missense Mutation (SNP) | VAF 158/312 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.676); catalogued as COSV55568165; called by muse, varscan2
- LRP2 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 144/294 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.107); catalogued as rs759579869, COSV55566644; called by muse, mutect2, varscan2
- LRPPRC | c.1474C>T p.R492* | Nonsense Mutation (SNP) | VAF 191/421 reads (45%) | catalogued as COSV53235302; called by muse, mutect2, varscan2
- LRRC4B | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 186/509 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs753871188; called by muse, mutect2, varscan2
- LTB4R2 | c.631G>A p.A211T (on ENST00000528054; = p.A180T on NM_019839.5) | Missense Mutation (SNP) | VAF 446/863 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.098); catalogued as rs1304988906; called by muse, mutect2, varscan2
- LY75 | c.2800_2802del p.N934del | In Frame Del (DEL) | VAF 112/269 reads (42%) | catalogued as rs959727947; called by mutect2, pindel, varscan2
- LZTR1 | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 185/390 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs747430075, COSV53147792; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MAP10 | c.926G>A p.R309Q | Missense Mutation (SNP) | VAF 291/684 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV69362768; called by muse, mutect2, varscan2
- MAP1B | c.7055C>T p.P2352L | Missense Mutation (SNP) | VAF 160/314 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as COSV57099506; called by muse, mutect2, varscan2
- MAP3K12 | c.1811G>A p.R604H | Missense Mutation (SNP) | VAF 325/709 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.375); catalogued as rs754240127, COSV57231852; called by muse, mutect2, varscan2
- MAP4K4 | c.1513C>T p.R505W | Missense Mutation (SNP) | VAF 157/336 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs765227761; called by muse, mutect2, varscan2
- MAPK12 | c.442G>A p.G148S | Missense Mutation (SNP) | VAF 221/509 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs746411853; called by muse, mutect2, varscan2
- MARK4 | c.620C>T p.T207M | Missense Mutation (SNP) | VAF 288/583 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.322); catalogued as rs968227279, COSV53467631; called by muse, mutect2, varscan2
- MBD5 | c.3530A>G p.N1177S | Missense Mutation (SNP) | VAF 116/321 reads (36%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs1413458459; called by muse, mutect2, varscan2
- MBD6 | c.2012dup p.T672Yfs*45 | Frame Shift Ins (INS) | VAF 42/116 reads (36%) | catalogued as rs750430563; called by mutect2, varscan2
- MCM3 | c.1010G>A p.R337Q (on ENST00000229854 / NM_001366374.2; = p.R327Q on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 141/341 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as COSV57717393; called by muse, mutect2, varscan2
- MED13L | c.1589C>T p.A530V | Missense Mutation (SNP) | VAF 173/343 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.346); catalogued as rs761541301, COSV56126143; called by muse, mutect2, varscan2
- MEIS2 | c.904C>T p.P302S (on ENST00000561208 / NM_170675.5; = p.P289S on NM_002399.3) | Missense Mutation (SNP) | VAF 79/290 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV99575916; called by muse, varscan2
- MFSD14B | c.424G>A p.G142R | Missense Mutation (SNP) | VAF 68/181 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64700989; called by muse, mutect2, varscan2
- MFSD8 | c.831dup p.V278Cfs*10 | Frame Shift Ins (INS) | VAF 111/292 reads (38%) | catalogued as rs775699005; called by mutect2, pindel, varscan2
- MGAT3 | c.384del p.P130Rfs*24 | Frame Shift Del (DEL) | VAF 264/670 reads (39%) | catalogued as rs768261467, COSV57864436; called by mutect2, pindel, varscan2
- MGAT5B | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 34/521 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV56927340; called by muse, mutect2
- MICAL3 | c.2356C>T p.R786W | Missense Mutation (SNP) | VAF 275/590 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780610274; called by muse, mutect2, varscan2
- MICALL1 | c.1451G>A p.S484N | Missense Mutation (SNP) | VAF 225/465 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV53241242; called by muse, mutect2, varscan2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 272/596 reads (46%) | catalogued as rs762448666; called by mutect2, pindel, varscan2
- MIEF2 | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 50/868 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as COSV59901478, COSV59902397; called by muse, mutect2
- MIOX | c.739C>T p.R247W | Missense Mutation (SNP) | VAF 175/348 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.673); catalogued as rs769716685; called by muse, mutect2, varscan2
- MIXL1 | c.253T>C p.S85P | Missense Mutation (SNP) | VAF 267/594 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs780097140, COSV64729016; called by muse, mutect2, varscan2
- MLEC | c.776G>A p.R259H | Missense Mutation (SNP) | VAF 20/664 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV57330380; called by muse, mutect2
- MMRN2 | c.2450C>T p.A817V | Missense Mutation (SNP) | VAF 224/421 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs760475843; called by muse, mutect2, varscan2
- MNDA | c.164del p.K55Sfs*8 | Frame Shift Del (DEL) | VAF 110/345 reads (32%) | catalogued as rs750084919, COSV100933258; called by mutect2, pindel, varscan2
- MNX1 | c.374_375insTGCCGC p.A133_A134dup | In Frame Ins (INS) | VAF 19/60 reads (32%) | catalogued as rs1240163222; called by pindel, varscan2
- MOB3C | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 305/648 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs141351633; called by muse, mutect2, varscan2
- MOS | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 272/536 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV61336392; called by muse, mutect2, varscan2
- MPDZ | c.2209G>A p.G737S | Missense Mutation (SNP) | VAF 116/264 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs73406290; called by muse, mutect2, varscan2
- MPP3 | c.1246G>A p.A416T | Missense Mutation (SNP) | VAF 136/260 reads (52%) | SIFT tolerated (0.73); PolyPhen benign (0.285); catalogued as rs765597486, COSV68198768; called by muse, varscan2
- MPPED1 | c.823G>A p.V275I | Missense Mutation (SNP) | VAF 223/471 reads (47%) | SIFT tolerated (0.39); PolyPhen benign (0.023); catalogued as rs981610664, COSV68837719; called by muse, mutect2, varscan2
- MRC2 | c.2390C>T p.A797V | Missense Mutation (SNP) | VAF 301/643 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.115); catalogued as rs781455215; called by muse, varscan2
- MROH2A | c.1457G>A p.R486H | Missense Mutation (SNP) | VAF 113/213 reads (53%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs766903289; called by muse, mutect2, varscan2
- MROH7 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 128/457 reads (28%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs531104510, COSV59878973; called by muse, mutect2, varscan2
- MSANTD4 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 161/308 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.101); catalogued as rs1177741904; called by muse, mutect2, varscan2
- MTREX | c.2626G>A p.V876M | Missense Mutation (SNP) | VAF 21/296 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1374716977; called by muse, mutect2
- MTUS2 | c.2316G>T p.L772F | Missense Mutation (SNP) | VAF 151/315 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV101462302, COSV70915725; called by muse, mutect2, varscan2
- MUC12 | c.7933A>G p.T2645A (on ENST00000379442; = p.T2502A on NM_001164462.1) | Missense Mutation (SNP) | VAF 200/3594 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.596); catalogued as COSV65183950; called by muse, mutect2
- MUC12 | c.12167G>A p.R4056H (on ENST00000379442; = p.R3913H on NM_001164462.1) | Missense Mutation (SNP) | VAF 52/1060 reads (5%) | SIFT tolerated (0.53); catalogued as rs1240146329; called by muse, mutect2
- MUC16 | c.43327C>T p.P14443S | Missense Mutation (SNP) | VAF 155/346 reads (45%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.001); catalogued as rs376292030, COSV66694071; called by muse, mutect2
- MUC5AC | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 324/675 reads (48%) | SIFT deleterious (0); catalogued as rs777497677, COSV100650564; called by muse, mutect2, varscan2
- MUTYH | c.337C>T p.R113W | Missense Mutation (SNP) | VAF 120/257 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs373766973; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH13 | c.1886C>T p.A629V | Missense Mutation (SNP) | VAF 67/212 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as rs1388879579; called by muse, mutect2, varscan2
- MYH6 | c.2619G>T p.K873N | Missense Mutation (SNP) | VAF 296/616 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV62451586, COSV62454573; called by muse, mutect2, varscan2
- MYLK4 | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 121/238 reads (51%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs771991937, COSV51138930; called by muse, mutect2, varscan2
- MYO16 | c.686C>T p.A229V | Missense Mutation (SNP) | VAF 71/171 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as rs1200947622, COSV51780421; called by muse, mutect2, varscan2
- MYO16 | c.4752del p.A1585Rfs*18 | Frame Shift Del (DEL) | VAF 87/244 reads (36%) | catalogued as rs900383313; called by mutect2, pindel, varscan2
- MYORG | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 298/621 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as rs867197049, COSV52626441; called by muse, mutect2, varscan2
- N4BP2L2 | c.223A>G p.T75A | Missense Mutation (SNP) | VAF 122/275 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV57230267; called by muse, mutect2, varscan2
- NAALAD2 | c.890G>A p.R297H | Missense Mutation (SNP) | VAF 67/146 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as rs775425061, COSV58964937; called by muse, mutect2, varscan2
- NAGK | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 110/288 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.425); catalogued as rs183509027, COSV99730580; called by muse, mutect2, varscan2
- NAPG | c.614T>C p.L205P | Missense Mutation (SNP) | VAF 148/262 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs577374742; called by muse, mutect2, varscan2
- NAV3 | c.4333C>T p.R1445C | Missense Mutation (SNP) | VAF 165/362 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760922961, COSV57078990, COSV57117271; called by muse, mutect2, varscan2
- NCOA5 | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 288/600 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as rs779145499, COSV51644075; called by muse, mutect2, varscan2
- NDOR1 | c.254C>T p.T85I | Missense Mutation (SNP) | VAF 195/401 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.381); catalogued as rs1203595729; called by muse, mutect2, varscan2
- NDUFS1 | c.413A>T p.D138V | Missense Mutation (SNP) | VAF 131/329 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51913758; called by muse, mutect2, varscan2
- NELFCD | c.1198G>A p.E400K (on ENST00000602795; = p.E382K on NM_198976.4) | Missense Mutation (SNP) | VAF 177/388 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs1228209181, COSV53883664; called by muse, mutect2, varscan2
- NFKBID | c.892C>T p.R298W (on ENST00000396901; = p.R450W on NM_032721.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 196/399 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs753586676; called by muse, mutect2, varscan2
- NINL | c.2107G>A p.G703S | Missense Mutation (SNP) | VAF 64/940 reads (7%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs781399245, COSV54005687; called by muse, mutect2
- NKX2-5 | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 339/752 reads (45%) | SIFT tolerated (0.52); PolyPhen benign (0.214); catalogued as COSV100234812; called by muse, mutect2, varscan2
- NLGN2 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 332/672 reads (49%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as rs1085307473, COSV100192957; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NME7 | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 82/188 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs141747474; called by muse, mutect2, varscan2
- NPAP1 | c.145G>A p.G49S | Missense Mutation (SNP) | VAF 84/1462 reads (6%) | SIFT tolerated (0.6); PolyPhen benign (0.038); catalogued as COSV61510326; called by muse, mutect2
- NPHP3 | c.3353G>A p.R1118H | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs749623594; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NPTN | c.193T>C p.W65R | Missense Mutation (SNP) | VAF 232/664 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54737162; called by muse, varscan2
- NREP | c.205del p.*69Nfs*59 | Frame Shift Del (DEL) | VAF 95/281 reads (34%) | catalogued as COSV57405086; called by mutect2, pindel, varscan2
- NRIP2 | c.775G>A p.G259R | Missense Mutation (SNP) | VAF 197/414 reads (48%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as rs1427270593; called by muse, mutect2, varscan2
- NRP2 | c.1126C>T p.R376W | Missense Mutation (SNP) | VAF 145/322 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99784984; called by muse, mutect2
- NRXN1 | c.320C>T p.T107M | Missense Mutation (SNP) | VAF 348/722 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs368549770, COSV68027100; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NTN5 | c.1312G>A p.D438N | Missense Mutation (SNP) | VAF 384/708 reads (54%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs775613587; called by muse, varscan2
- NUAK2 | c.802C>T p.R268W | Missense Mutation (SNP) | VAF 121/306 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs202048409; called by muse, mutect2, varscan2
- NUMA1 | c.3020C>T p.A1007V | Missense Mutation (SNP) | VAF 361/693 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.05); catalogued as rs141626208; called by muse, mutect2, varscan2
- NUP188 | c.4937C>T p.T1646M | Missense Mutation (SNP) | VAF 169/357 reads (47%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.451); catalogued as rs140889124; called by muse, mutect2, varscan2
- NYX | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 453/454 reads (100%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100699387; called by muse, mutect2, varscan2
- ODF2 | c.2324G>A p.R775Q (on ENST00000434106 / NM_153433.2; = p.R751Q on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 127/455 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.138); catalogued as rs751189855; called by muse, mutect2, varscan2
- ODR4 | c.999del p.D334Ifs*22 | Frame Shift Del (DEL) | VAF 93/193 reads (48%) | catalogued as rs776869231; called by mutect2, varscan2
- OLFM4 | c.1297G>A p.A433T | Missense Mutation (SNP) | VAF 25/396 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.264); catalogued as rs748620508; called by muse, mutect2
- OLFML2A | c.869del p.G290Afs*12 | Frame Shift Del (DEL) | VAF 327/817 reads (40%) | catalogued as COSV56583973; called by mutect2, pindel, varscan2
- OR10G4 | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 172/376 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.248); catalogued as rs767067867; called by muse, mutect2
- OR13C8 | c.872T>G p.L291R | Missense Mutation (SNP) | VAF 67/209 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV58612308; called by muse, mutect2, varscan2
- OR1J2 | c.321del p.F107Lfs*30 | Frame Shift Del (DEL) | VAF 131/337 reads (39%) | catalogued as COSV99080418; called by mutect2, pindel, varscan2
- OR2A7 | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 144/914 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs747860889, COSV71828208; called by muse, varscan2
- OR4C6 | c.674C>G p.S225C | Missense Mutation (SNP) | VAF 150/319 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV58602612; called by muse, mutect2, varscan2
- OR4P4 | c.916C>A p.L306M | Missense Mutation (SNP) | VAF 125/126 reads (99%) | SIFT tolerated (0.11); PolyPhen benign (0.276); catalogued as COSV100111525; called by muse, mutect2, varscan2
- OR5M11 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 153/318 reads (48%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs778688024, COSV73141978; called by muse, mutect2, varscan2
- OR6X1 | c.473C>T p.T158M | Missense Mutation (SNP) | VAF 138/303 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.046); catalogued as rs755233085, COSV60009776; called by muse, mutect2, varscan2
- OR8J1 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 139/426 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV57316544; called by muse, mutect2, varscan2
- OSBPL7 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 175/368 reads (48%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.877); catalogued as rs201720672; called by muse, mutect2, varscan2
- OSGEPL1 | c.36del p.F12Lfs*12 | Frame Shift Del (DEL) | VAF 59/134 reads (44%) | catalogued as rs750679212; called by mutect2, varscan2
- OVCH2 | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 132/268 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs920172894, COSV71952759; called by muse, mutect2, varscan2
- P4HA3 | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 137/305 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as rs558949308; called by muse, mutect2, varscan2
- PADI3 | c.560C>T p.T187M | Missense Mutation (SNP) | VAF 200/436 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as rs146396025; called by muse, mutect2, varscan2
- PAK3 | c.1618C>T p.L540F (on ENST00000262836 / NM_001324328.2; = p.L525F on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 175/175 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs377015001; called by muse, mutect2, varscan2
- PAK5 | c.869C>T p.S290L | Missense Mutation (SNP) | VAF 222/489 reads (45%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.033); catalogued as rs559720359, COSV62032667, COSV62039060; called by muse, mutect2, varscan2
- PAPPA2 | c.1732C>T p.R578* | Nonsense Mutation (SNP) | VAF 211/455 reads (46%) | catalogued as rs375941290; called by muse, mutect2, varscan2
- PAWR | c.309del p.G104Afs*71 | Frame Shift Del (DEL) | VAF 299/776 reads (39%) | catalogued as rs1180183970; called by mutect2, pindel, varscan2
- PAX5 | c.644C>T p.P215L | Missense Mutation (SNP) | VAF 289/549 reads (53%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as rs1220530661, COSV63905829, COSV63909100; called by muse, mutect2, varscan2
- PAX5 | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 205/425 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.096); catalogued as rs1223489007, COSV63910034; called by muse, mutect2, varscan2
- PAXBP1 | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 120/278 reads (43%) | SIFT tolerated (0.53); PolyPhen benign (0.275); catalogued as rs369771025; called by muse, mutect2, varscan2
- PCDH1 | c.2453A>G p.N818S | Missense Mutation (SNP) | VAF 243/518 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758138536; called by muse, mutect2, varscan2
- PCDHA10 | c.289C>T p.R97W | Missense Mutation (SNP) | VAF 356/753 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.084); catalogued as rs782782390, COSV100256003; called by muse, mutect2, varscan2
- PCDHA12 | c.1427C>T p.T476M | Missense Mutation (SNP) | VAF 450/918 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs781884794, COSV100250504; called by muse, mutect2, varscan2
- PCDHA12 | c.1904G>A p.R635H | Missense Mutation (SNP) | VAF 229/528 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.911); catalogued as COSV56525069; called by muse, mutect2, varscan2
- PCDHA4 | c.1295C>T p.S432L | Missense Mutation (SNP) | VAF 261/573 reads (46%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.1); catalogued as rs781996796, COSV63538670, COSV63538981; called by muse, mutect2, varscan2
- PCDHB16 | c.2083del p.A695Pfs*45 | Frame Shift Del (DEL) | VAF 335/1014 reads (33%) | catalogued as COSV99501032; called by mutect2, pindel, varscan2
- PCDHB2 | c.1964C>T p.S655L | Missense Mutation (SNP) | VAF 601/1262 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs781921096, COSV50622181; called by muse, mutect2, varscan2
- PCDHB4 | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 18/390 reads (5%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as COSV52019831; called by muse, mutect2
- PCDHGB4 | c.2266C>T p.H756Y | Missense Mutation (SNP) | VAF 127/274 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.492); catalogued as rs768850867; called by muse, mutect2, varscan2
- PCIF1 | c.1519G>A p.V507I | Missense Mutation (SNP) | VAF 330/673 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1001133934; called by muse, varscan2
- PCNX2 | c.2691+1G>A p.X897_splice | Splice Site (SNP) | VAF 119/244 reads (49%) | catalogued as rs1206599005, COSV99269212; called by muse, mutect2, varscan2
- PDE1C | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 227/526 reads (43%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.816); catalogued as rs193921048; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PDE4D | c.1252C>T p.R418W (on ENST00000340635 / NM_001104631.2; = p.R282W on NM_006203.4) | Missense Mutation (SNP) | VAF 102/224 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs750666346; called by muse, varscan2
- PDZRN3 | c.2288G>A p.S763N | Missense Mutation (SNP) | VAF 40/645 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1345179125; called by muse, mutect2
- PDZRN4 | c.395del p.G132Afs*96 | Frame Shift Del (DEL) | VAF 92/256 reads (36%) | catalogued as rs1203008747; called by mutect2, pindel, varscan2
- PEMT | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 315/641 reads (49%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs773175169, COSV55131385; called by muse, mutect2, varscan2
- PER1 | c.3130G>A p.E1044K | Missense Mutation (SNP) | VAF 288/601 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.195); catalogued as rs771848468; called by muse, mutect2, varscan2
- PFKFB1 | c.993G>A p.A331= | Splice Region (SNP) | VAF 183/183 reads (100%) | catalogued as rs758972099, COSV66628839; called by muse, mutect2, varscan2
- PGLS | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 118/268 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.183); catalogued as rs1255128887; called by muse, mutect2, varscan2
- PGLS | c.733G>A p.A245T | Missense Mutation (SNP) | VAF 335/705 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as rs748266870, COSV99395762, COSV99395820; called by muse, mutect2, varscan2
- PHLDB1 | c.2282C>T p.A761V | Missense Mutation (SNP) | VAF 242/560 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs782664892, COSV100616646; called by muse, mutect2, varscan2
- PHOSPHO2 | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 68/179 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs770332213; called by muse, mutect2, varscan2
- PIBF1 | c.724C>T p.R242C | Missense Mutation (SNP) | VAF 137/281 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753442090; called by muse, mutect2, varscan2
- PIDD1 | c.2633G>A p.R878H | Missense Mutation (SNP) | VAF 404/780 reads (52%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs779799557, COSV57194762; called by muse, mutect2, varscan2
- PIGB | c.1240G>A p.V414I | Missense Mutation (SNP) | VAF 287/443 reads (65%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.479); catalogued as rs772121535; called by muse, mutect2, varscan2
- PIH1D1 | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 51/607 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs370272341; called by muse, mutect2
- PIK3R2 | c.1033C>T p.R345W | Missense Mutation (SNP) | VAF 148/349 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55846675, COSV55847040; called by muse, mutect2, varscan2
- PIKFYVE | c.5095G>A p.G1699R | Missense Mutation (SNP) | VAF 95/197 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.143); catalogued as COSV100011657; called by muse, mutect2, varscan2
- PINLYP | c.512del p.G171Afs*28 | Frame Shift Del (DEL) | VAF 170/393 reads (43%) | catalogued as COSV99746788; called by mutect2, pindel, varscan2
- PKD1 | c.9764G>A p.R3255H | Missense Mutation (SNP) | VAF 260/530 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1052458360; called by muse, varscan2
- PKHD1L1 | c.981del p.K328Nfs*15 | Frame Shift Del (DEL) | VAF 84/236 reads (36%) | catalogued as rs778197289; called by pindel, varscan2
- PKLR | c.644G>A p.G215D | Missense Mutation (SNP) | VAF 385/846 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.065); catalogued as rs1052308239, CD090472; called by muse, mutect2, varscan2
- PLA2G4F | c.1460G>A p.R487H | Missense Mutation (SNP) | VAF 124/423 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.397); catalogued as rs780466564; called by muse, mutect2, varscan2
- PLCE1 | c.2635C>T p.R879C | Missense Mutation (SNP) | VAF 259/564 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as rs372756642; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLCG2 | c.1127G>A p.R376Q | Missense Mutation (SNP) | VAF 242/470 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.609); catalogued as COSV63869352; called by muse, mutect2, varscan2
- PLD2 | c.2216G>A p.R739H | Missense Mutation (SNP) | VAF 217/540 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs373174584; called by muse, varscan2
- PLEC | c.1823A>G p.Y608C (on ENST00000322810 / NM_201380.4; = p.Y498C on NM_000445.5) | Missense Mutation (SNP) | VAF 172/385 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100520049; called by muse, mutect2, varscan2
- PLEKHG5 | c.1750G>A p.A584T (on ENST00000400915 / NM_001042663.3; = p.A547T on NM_020631.6) | Missense Mutation (SNP) | VAF 393/861 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.225); catalogued as rs769066586; called by muse, mutect2, varscan2
- PLEKHM1 | c.2225del p.G742Afs*14 | Frame Shift Del (DEL) | VAF 195/650 reads (30%) | catalogued as rs755096635; called by mutect2, pindel, varscan2
- PLXNA1 | c.1523C>T p.T508M | Missense Mutation (SNP) | VAF 227/498 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as rs748424966, COSV52527570; called by muse, mutect2
- PLXNA2 | c.1613C>T p.S538F | Missense Mutation (SNP) | VAF 130/261 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as rs756541044; called by muse, mutect2, varscan2
- PLXNB1 | c.5605+1G>A p.X1869_splice | Splice Site (SNP) | VAF 135/267 reads (51%) | catalogued as rs762123376, COSV56492732; called by muse, mutect2, varscan2
- PLXND1 | c.3895C>T p.R1299C | Missense Mutation (SNP) | VAF 32/594 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM1312171; called by muse, mutect2
- PMM2 | c.178+2_178+11del p.X60_splice | Splice Site (DEL) | VAF 30/130 reads (23%) | catalogued as rs1371941679; called by mutect2, varscan2
- PNPLA6 | c.1093C>T p.R365W (on ENST00000414982 / NM_001166111.2; = p.R317W on NM_006702.5) | Missense Mutation (SNP) | VAF 428/845 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs767812620; called by muse, mutect2, varscan2
- POLD1 | c.2360C>T p.P787L | Missense Mutation (SNP) | VAF 384/709 reads (54%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as rs199783227, COSV101486765; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLE | c.6088del p.A2030Pfs*18 | Frame Shift Del (DEL) | VAF 313/769 reads (41%) | catalogued as rs1060500809; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- POM121L12 | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 463/894 reads (52%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as rs1284258270, COSV101374890; called by muse, mutect2, varscan2
- POSTN | c.628C>T p.R210* | Nonsense Mutation (SNP) | VAF 87/189 reads (46%) | catalogued as COSV65711737; called by muse, varscan2
- PPFIA2 | c.793G>A p.D265N | Missense Mutation (SNP) | VAF 66/210 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.213); catalogued as rs200667643; called by muse, mutect2, varscan2
- PPIL3 | c.349G>A p.V117I (on ENST00000392283 / NM_130906.3; = p.V121I on NM_032472.4) | Missense Mutation (SNP) | VAF 106/233 reads (45%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as rs61730410, COSV53768973; called by muse, mutect2, varscan2
- PPP1CA | c.968G>A p.R323H | Missense Mutation (SNP) | VAF 174/390 reads (45%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.79); catalogued as rs766862399, COSV100335098; called by muse, mutect2, varscan2
- PPP1R12B | c.2633G>T p.S878I | Missense Mutation (SNP) | VAF 159/339 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV51782839; called by muse, mutect2, varscan2
- PPP1R12C | c.1111C>G p.P371A | Missense Mutation (SNP) | VAF 264/540 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.025); catalogued as COSV54735695; called by mutect2, varscan2
- PPP1R21 | c.1646G>A p.R549H | Missense Mutation (SNP) | VAF 185/361 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs144544742; called by muse, mutect2, varscan2
- PPP1R26 | c.2878G>A p.V960I | Missense Mutation (SNP) | VAF 37/633 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs779523294, COSV63355292; called by muse, mutect2
- PPP3CA | c.1466C>T p.A489V | Missense Mutation (SNP) | VAF 206/431 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV59918990; called by muse, mutect2, varscan2
- PRKAR2A | c.803C>T p.S268L | Missense Mutation (SNP) | VAF 103/235 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.147); catalogued as COSV55551276; called by muse, mutect2, varscan2
- PRKCE | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 189/411 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60317710; called by muse, mutect2, varscan2
- PRPF39 | c.421C>T p.R141W | Missense Mutation (SNP) | VAF 68/175 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs768524269, COSV63276804; called by muse, varscan2
- PRPF40B | c.41del p.P14Hfs*11 (on ENST00000380281; = p.P8Hfs*11 on NM_012272.3) | Frame Shift Del (DEL) | VAF 62/112 reads (55%) | catalogued as COSV56060022; called by mutect2, varscan2
- PRPS1L1 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 142/342 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1336330353, COSV72649781; called by muse, mutect2, varscan2
- PRRC2A | c.5315G>A p.R1772H | Missense Mutation (SNP) | VAF 135/356 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs751160523; called by muse, mutect2, varscan2
- PRSS3 | c.401C>G p.T134S (on ENST00000361005 / NM_007343.4; = p.T242S on NM_002771.3) | Missense Mutation (SNP) | VAF 115/234 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.423); catalogued as COSV61554640; called by muse, mutect2, varscan2
- PRSS53 | c.1526C>T p.A509V | Missense Mutation (SNP) | VAF 250/573 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.864); catalogued as rs1228843319, COSV54924443; called by muse, mutect2, varscan2
- PRXL2A | c.218dup p.N73Kfs*48 | Frame Shift Ins (INS) | VAF 109/216 reads (50%) | catalogued as rs377622179; called by mutect2, varscan2
- PSD | c.2663G>A p.R888H | Missense Mutation (SNP) | VAF 212/470 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs370939613; called by muse, mutect2, varscan2
- PSMB8 | c.472A>G p.M158V (on ENST00000374882 / NM_148919.4; = p.M154V on NM_004159.5) | Missense Mutation (SNP) | VAF 253/555 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.231); catalogued as rs543204360; called by muse, mutect2, varscan2
- PSMB8 | c.31del p.R11Efs*74 | Frame Shift Del (DEL) | VAF 339/962 reads (35%) | catalogued as rs775701157; called by pindel, varscan2
- PSMF1 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 260/549 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.039); catalogued as rs773658311; called by muse, mutect2, varscan2
- PTCH1 | c.1925del p.P642Hfs*51 | Frame Shift Del (DEL) | VAF 272/684 reads (40%) | catalogued as CD054407; called by mutect2, pindel, varscan2
- PTF1A | c.263dup p.L89Pfs*3 | Frame Shift Ins (INS) | VAF 405/1051 reads (39%) | catalogued as rs902163516; called by mutect2, pindel, varscan2
- PTK2B | c.2098C>T p.R700* | Nonsense Mutation (SNP) | VAF 125/276 reads (45%) | catalogued as rs756238630; called by muse, mutect2, varscan2
- PTPN21 | c.2299G>A p.A767T | Missense Mutation (SNP) | VAF 457/996 reads (46%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as rs1051803201; called by muse, mutect2, varscan2
- PTPRF | c.2884C>T p.Q962* | Nonsense Mutation (SNP) | VAF 283/571 reads (50%) | catalogued as rs766805311; called by muse, mutect2, varscan2
- PTPRK | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 116/296 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.142); catalogued as rs1323042656; called by muse, mutect2, varscan2
- PTPRN | c.92del p.G31Afs*75 | Frame Shift Del (DEL) | VAF 187/408 reads (46%) | catalogued as rs1179811215; called by mutect2, pindel, varscan2
- PTPRN2 | c.139G>A p.G47R | Missense Mutation (SNP) | VAF 376/718 reads (52%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs780462698; called by muse, mutect2, varscan2
- PTPRS | c.2936G>A p.R979Q | Missense Mutation (SNP) | VAF 62/772 reads (8%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs1193352037, COSV53611844; called by muse, mutect2
- PTPRZ1 | c.3248C>T p.A1083V | Missense Mutation (SNP) | VAF 142/272 reads (52%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); catalogued as rs778883937, COSV66431774; called by muse, mutect2, varscan2
- PWWP3A | c.869C>T p.S290L (on ENST00000627377; = p.S289L on NM_032853.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 330/707 reads (47%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs1298281521, COSV60903447; called by muse, mutect2, varscan2
- PXDNL | c.817T>G p.S273A | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as COSV100684090, COSV62479258; called by muse, mutect2
- QTRT2 | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 151/390 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.49); catalogued as rs777246405; called by muse, mutect2, varscan2
- RASAL1 | c.2066C>T p.A689V | Missense Mutation (SNP) | VAF 281/653 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as rs749908078; called by muse, mutect2, varscan2
- RASGRF2 | c.3578G>A p.R1193H | Missense Mutation (SNP) | VAF 140/309 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as rs755935956, COSV54132686, COSV54138609; called by muse, mutect2, varscan2
- RBM14 | c.712C>T p.R238W | Missense Mutation (SNP) | VAF 46/714 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.639); catalogued as rs750468092, COSV59559185; called by muse, mutect2
- RBM34 | c.1235C>T p.T412M | Missense Mutation (SNP) | VAF 154/336 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.183); catalogued as rs188131274; called by muse, mutect2, varscan2
- RBM47 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 432/844 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs773284491, COSV99921314; called by muse, mutect2, varscan2
- RBMXL1 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 22/649 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.231); catalogued as COSV53098008; called by muse, mutect2
- RBMXL2 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 300/582 reads (52%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.971); catalogued as COSV60979613; called by muse, mutect2, varscan2
- RBMXL3 | c.2051G>A p.R684H | Missense Mutation (SNP) | VAF 323/330 reads (98%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.355); catalogued as rs201303575, COSV57750455; called by muse, mutect2, varscan2
- RC3H1 | c.2036C>T p.P679L | Missense Mutation (SNP) | VAF 164/354 reads (46%) | SIFT tolerated (0.64); PolyPhen benign (0.023); catalogued as rs1455639757; called by muse, mutect2, varscan2
- RCOR3 | c.1394G>A p.R465H | Missense Mutation (SNP) | VAF 265/498 reads (53%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.976); catalogued as rs1350236018, COSV65365749; called by muse, mutect2, varscan2
- RECK | c.1877G>A p.R626H | Missense Mutation (SNP) | VAF 95/224 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as rs761442720; called by muse, mutect2, varscan2
- RECQL | c.1781C>T p.T594M | Missense Mutation (SNP) | VAF 78/166 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.326); catalogued as rs372947261; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RFPL3 | c.499G>A p.V167I (on ENST00000249007 / NM_001098535.1; = p.V138I on NM_006604.2) | Missense Mutation (SNP) | VAF 191/476 reads (40%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs780830944, COSV50750750; called by muse, mutect2, varscan2
- RGS12 | c.2170G>A p.V724I | Missense Mutation (SNP) | VAF 205/512 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs147160362; called by muse, mutect2, varscan2
- RGS3 | c.3542G>A p.R1181H (on ENST00000350696 / NM_001282923.2; = p.R900H on NM_130795.4) | Missense Mutation (SNP) | VAF 203/441 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs140250676; called by muse, mutect2, varscan2
- RIPK2 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 32/281 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs763096134, COSV55131345; called by muse, mutect2, varscan2
- RIPK4 | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 167/349 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs147599366, COSV60185367; called by muse, mutect2, varscan2
- RIPOR3 | c.1007G>A p.S336N | Missense Mutation (SNP) | VAF 141/326 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as rs1410924817, COSV50390511; called by muse, mutect2, varscan2
- RLBP1 | c.90T>A p.H30Q | Missense Mutation (SNP) | VAF 218/675 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs746395372; called by muse, mutect2, varscan2
- RNF213 | c.8206G>A p.V2736I | Missense Mutation (SNP) | VAF 169/343 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs754574537; called by muse, mutect2, varscan2
- RNH1 | c.1202G>A p.R401H | Missense Mutation (SNP) | VAF 411/848 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs751047045, COSV100339396, COSV57277143; called by muse, mutect2, varscan2
- RP1 | c.431T>C p.V144A | Missense Mutation (SNP) | VAF 348/808 reads (43%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV55120184; called by muse, mutect2, varscan2
- RPGRIP1L | c.3475A>G p.N1159D | Missense Mutation (SNP) | VAF 95/271 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0.219); catalogued as rs774549370; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RPH3AL | c.895C>T p.R299* | Nonsense Mutation (SNP) | VAF 263/553 reads (48%) | catalogued as rs753137177, COSV58745637; called by muse, mutect2, varscan2
- RPS24 | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 113/248 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1174271255; called by muse, mutect2, varscan2
- RPS6KB1 | c.325C>T p.R109* | Nonsense Mutation (SNP) | VAF 110/251 reads (44%) | catalogued as COSV99847614; called by muse, mutect2, varscan2
- RPTOR | c.1864G>A p.A622T | Missense Mutation (SNP) | VAF 229/451 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs769317295, COSV60811446; called by muse, mutect2, varscan2
- RRAGB | c.632G>A p.R211H (on ENST00000262850 / NM_016656.4; = p.R183H on NM_006064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 124/124 reads (100%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.806); catalogued as rs767125784, COSV53331894; called by muse, mutect2, varscan2
- RREB1 | c.2180G>A p.R727H | Missense Mutation (SNP) | VAF 302/670 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs200263205, COSV58552777; called by muse, mutect2, varscan2
- RREB1 | c.5015C>T p.P1672L | Missense Mutation (SNP) | VAF 318/658 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.022); catalogued as rs1473423709; called by muse, mutect2, varscan2
- RSPH14 | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 258/594 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.232); catalogued as rs1476035687, COSV53270361; called by muse, mutect2, varscan2
- RSPH6A | c.779G>A p.R260Q | Missense Mutation (SNP) | VAF 319/620 reads (51%) | SIFT tolerated (0.36); PolyPhen benign (0.095); catalogued as rs576206235; called by muse, mutect2, varscan2
- RTP2 | c.74A>G p.D25G | Missense Mutation (SNP) | VAF 230/449 reads (51%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as rs1317032774; called by muse, mutect2, varscan2
- RXFP3 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 293/638 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57505221; called by muse, mutect2, varscan2
- RXFP3 | c.1374dup p.R459Afs*37 | Frame Shift Ins (INS) | VAF 313/809 reads (39%) | catalogued as rs756773263; called by mutect2, pindel, varscan2
- RYR1 | c.5038G>A p.V1680M | Missense Mutation (SNP) | VAF 335/685 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1161726783, COSV100616697; called by muse, mutect2, varscan2
- RYR3 | c.8092C>T p.R2698W (on ENST00000389232; = p.R2699W on NM_001036.6) | Missense Mutation (SNP) | VAF 159/505 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs368235252; called by muse, mutect2, varscan2
- SACS | c.3769G>A p.G1257R | Missense Mutation (SNP) | VAF 83/205 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.161); catalogued as rs767797830, CM138554, COSV101207742; called by muse, mutect2, varscan2
- SAFB | c.1870C>T p.R624C | Missense Mutation (SNP) | VAF 190/399 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as COSV52650979; called by muse, mutect2, varscan2
- SALL1 | c.2646G>T p.Q882H | Missense Mutation (SNP) | VAF 122/284 reads (43%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.969); catalogued as COSV99174899; called by muse, mutect2, varscan2
- SALL2 | c.1187C>T p.T396M | Missense Mutation (SNP) | VAF 200/442 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1181245709; called by muse, mutect2, varscan2
- SAMD1 | c.652C>T p.R218* | Nonsense Mutation (SNP) | VAF 20/344 reads (6%) | catalogued as COSV54116468; called by muse, mutect2
- SAMD9L | c.3893G>A p.R1298H | Missense Mutation (SNP) | VAF 119/227 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs1010548594, COSV59081032; called by muse, mutect2, varscan2
- SBNO2 | c.3538G>A p.A1180T | Missense Mutation (SNP) | VAF 486/1004 reads (48%) | SIFT tolerated (0.38); PolyPhen benign (0.124); catalogued as rs1199609438; called by muse, mutect2, varscan2
- SCARF2 | c.2527dup p.R843Pfs*214 | Frame Shift Ins (INS) | VAF 216/667 reads (32%) | catalogued as rs1326577677; called by mutect2, varscan2
- SCN1A | c.5298del p.F1766Lfs*13 (on ENST00000303395 / NM_001202435.3; = p.F1755Lfs*13 on NM_006920.6 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 176/435 reads (40%) | catalogued as CD044161, CD076901, CD1511223; called by mutect2, pindel, varscan2
- SCN1A | c.4766T>A p.V1589E (on ENST00000303395 / NM_001202435.3; = p.V1578E on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 198/433 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as CM1511237; called by muse, mutect2, varscan2
- SCN4A | c.3002G>A p.R1001H | Missense Mutation (SNP) | VAF 176/381 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.04); catalogued as rs770588235; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCNN1D | c.638C>T p.T213M (on ENST00000338555; = p.T377M on NM_001130413.4) | Missense Mutation (SNP) | VAF 159/425 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs143319964; called by muse, mutect2, varscan2
- SDK2 | c.6316G>A p.D2106N | Missense Mutation (SNP) | VAF 280/566 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.27); catalogued as rs199923333, COSV66194052; called by muse, varscan2
- SEC11C | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 123/234 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.14); catalogued as rs752087102, COSV55311932; called by muse, mutect2, varscan2
- SEC16A | c.2113G>A p.E705K | Missense Mutation (SNP) | VAF 224/476 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs765856747; called by muse, mutect2, varscan2
- SELENON | c.935A>G p.Q312R | Missense Mutation (SNP) | VAF 344/724 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as rs775897489, COSV100823421; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEMA5A | c.2746C>T p.R916C | Missense Mutation (SNP) | VAF 241/527 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs913733262; called by muse, mutect2, varscan2
- SEMA6B | c.2455C>T p.R819W | Missense Mutation (SNP) | VAF 388/750 reads (52%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.249); catalogued as rs1199714131; called by muse, varscan2
- SEMA6B | c.2314G>A p.G772S | Missense Mutation (SNP) | VAF 281/479 reads (59%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs1222889210; called by muse, mutect2, varscan2
- SERPINA9 | c.305T>G p.L102R | Missense Mutation (SNP) | VAF 159/432 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100099058; called by muse, mutect2, varscan2
- SERPINB11 | c.686C>T p.P229L | Missense Mutation (SNP) | VAF 147/360 reads (41%) | SIFT tolerated (0.68); PolyPhen benign (0.017); catalogued as rs572331029; called by muse, mutect2, varscan2
- SERPINB13 | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 114/266 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.457); catalogued as rs576283991, COSV54027789, COSV54028454; called by muse, varscan2
- SERPING1 | c.1211C>T p.T404M | Missense Mutation (SNP) | VAF 136/260 reads (52%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.967); catalogued as rs373751057, COSV99557825; called by muse, mutect2, varscan2
- SESN3 | c.842C>T p.A281V | Missense Mutation (SNP) | VAF 177/458 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs369321677; called by muse, mutect2, varscan2
- SETD5 | c.3456_3458del p.S1154del | In Frame Del (DEL) | VAF 130/304 reads (43%) | catalogued as rs780398522; called by pindel, varscan2
- SGCZ | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 162/340 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as rs779572116, COSV66019663; called by muse, mutect2, varscan2
- SH2D3A | c.1208G>A p.R403Q | Missense Mutation (SNP) | VAF 65/1211 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.772); catalogued as rs777699573, COSV55585229; called by muse, mutect2
- SH2D3C | c.679del p.R227Efs*46 (on ENST00000314830 / NM_170600.3; = p.R70Efs*46 on NM_005489.4) | Frame Shift Del (DEL) | VAF 145/382 reads (38%) | catalogued as rs1564415903; called by mutect2, pindel, varscan2
- SH3PXD2A | c.2587G>A p.A863T (on ENST00000369774 / NM_001365079.1; = p.A835T on NM_014631.2) | Missense Mutation (SNP) | VAF 311/661 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as rs766798828, COSV60116246; called by muse, mutect2, varscan2
- SHISA6 | c.985C>T p.R329W (on ENST00000409168 / NM_001173461.1; = p.R380W on NM_207386.4) | Missense Mutation (SNP) | VAF 221/407 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs759642966, COSV69384484; called by muse, mutect2, varscan2
- SIM1 | c.1324C>T p.R442C | Missense Mutation (SNP) | VAF 307/604 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); catalogued as rs572023033, COSV53489722, COSV53492285; called by muse, mutect2, varscan2
- SIPA1L3 | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 409/846 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55919611, COSV99730771; called by muse, varscan2
- SLC11A2 | c.767T>C p.V256A (on ENST00000394904 / NM_001379455.1; = p.V227A on NM_000617.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 88/191 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.273); catalogued as rs745901974; called by muse, mutect2, varscan2
- SLC12A6 | c.617del p.L206Yfs*28 (on ENST00000354181 / NM_001365088.1; = p.L155Yfs*28 on NM_005135.2) | Frame Shift Del (DEL) | VAF 142/477 reads (30%) | catalogued as rs916571899; called by mutect2, pindel, varscan2
- SLC16A2 | c.719G>A p.S240N | Missense Mutation (SNP) | VAF 308/308 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs12849479; called by muse, mutect2, varscan2
- SLC1A1 | c.935A>G p.N312S | Missense Mutation (SNP) | VAF 129/304 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.693); catalogued as COSV52058946; called by muse, mutect2, varscan2
- SLC20A2 | c.1354G>A p.V452M | Missense Mutation (SNP) | VAF 300/615 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.313); catalogued as rs370095133; called by muse, mutect2, varscan2
- SLC22A23 | c.1546C>T p.L516= | Splice Region (SNP) | VAF 167/367 reads (46%) | catalogued as rs142569200; called by muse, mutect2, varscan2
- SLC22A3 | c.1232C>T p.A411V | Missense Mutation (SNP) | VAF 139/358 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.474); catalogued as rs537020286, COSV51710586; called by muse, mutect2, varscan2
- SLC24A1 | c.3179C>T p.A1060V | Missense Mutation (SNP) | VAF 296/460 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs760183851, COSV56051315; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC25A29 | c.869C>T p.A290V (on ENST00000359232 / NM_001039355.3; = p.A224V on NM_152333.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 325/658 reads (49%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs777181473; called by muse, mutect2, varscan2
- SLC25A39 | c.506C>T p.A169V (on ENST00000377095 / NM_001143780.3; = p.A161V on NM_016016.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 175/359 reads (49%) | SIFT tolerated (0.25); PolyPhen benign (0.317); catalogued as rs750976898; called by muse, mutect2, varscan2
- SLC28A1 | c.1786del p.A596Lfs*9 | Frame Shift Del (DEL) | VAF 189/458 reads (41%) | catalogued as rs1567193952; called by mutect2, pindel, varscan2
- SLC34A1 | c.1691G>A p.R564Q | Missense Mutation (SNP) | VAF 266/637 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.82); catalogued as rs768399789; called by muse, mutect2, varscan2
- SLC35F1 | c.1142C>T p.P381L | Missense Mutation (SNP) | VAF 191/455 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.248); catalogued as rs140419570; called by muse, mutect2, varscan2
- SLC35G1 | c.571G>A p.V191M (on ENST00000427197 / NM_001134658.3; = p.V190M on NM_153226.4) | Missense Mutation (SNP) | VAF 70/289 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.028); catalogued as rs747756945; called by muse, mutect2, varscan2
- SLC52A3 | c.238G>T p.G80C | Missense Mutation (SNP) | VAF 184/475 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV54077617; called by muse, mutect2, varscan2
- SLC5A8 | c.1324G>A p.A442T | Missense Mutation (SNP) | VAF 91/198 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs372017110; called by muse, mutect2, varscan2
- SLC6A13 | c.967G>A p.G323S | Missense Mutation (SNP) | VAF 114/275 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.053); catalogued as rs536955832; called by muse, mutect2, varscan2
- SLC6A7 | c.832del p.Q278Sfs*82 | Frame Shift Del (DEL) | VAF 167/410 reads (41%) | catalogued as COSV57939345; called by mutect2, varscan2
- SLC7A10 | c.471del p.T158Pfs*12 | Frame Shift Del (DEL) | VAF 216/579 reads (37%) | catalogued as rs753589038, COSV53507811; called by mutect2, pindel, varscan2
- SLC7A9 | c.998G>A p.R333Q | Missense Mutation (SNP) | VAF 149/288 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as rs769576205, CM061205, COSV99195208; called by muse, varscan2
- SLC9A9 | c.1115C>T p.A372V | Missense Mutation (SNP) | VAF 99/226 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs761080781, COSV100339687; called by muse, mutect2, varscan2
- SLCO1B1 | c.1828C>T p.R610C | Missense Mutation (SNP) | VAF 122/254 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs748860610, COSV57007405; called by muse, varscan2
- SLF1 | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 130/290 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1255138443; called by muse, mutect2, varscan2
- SMAD5 | c.5C>T p.T2M | Missense Mutation (SNP) | VAF 74/151 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as rs375904750; called by muse, mutect2, varscan2
- SMG1 | c.5993G>A p.R1998H | Missense Mutation (SNP) | VAF 26/311 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs771153112; called by muse, mutect2
- SMO | c.1571C>T p.A524V | Missense Mutation (SNP) | VAF 180/401 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.652); catalogued as COSV50824992, COSV99977205; called by muse, varscan2
- SMYD1 | c.1216G>A p.A406T | Missense Mutation (SNP) | VAF 262/537 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs200376153; called by muse, mutect2, varscan2
- SNRNP200 | c.2183G>A p.R728Q | Missense Mutation (SNP) | VAF 124/266 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1477839027; called by muse, mutect2, varscan2
- SNX13 | c.1531C>T p.R511C | Missense Mutation (SNP) | VAF 119/280 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs960803553, COSV68067477; called by muse, mutect2, varscan2
- SOD2 | c.199_201del p.E67del | In Frame Del (DEL) | VAF 282/589 reads (48%) | catalogued as rs773283190; called by pindel, varscan2
- SOGA1 | c.820C>T p.R274W | Missense Mutation (SNP) | VAF 444/839 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52923616; called by muse, mutect2, varscan2
- SOX9 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 340/692 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV55427144; called by muse, mutect2, varscan2
- SPAG9 | c.3121T>G p.L1041V (on ENST00000262013 / NM_001130528.3; = p.L1027V on NM_003971.6) | Missense Mutation (SNP) | VAF 101/291 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.14); catalogued as rs1168492883; called by muse, mutect2, varscan2
- SPEG | c.4675G>A p.A1559T | Missense Mutation (SNP) | VAF 212/512 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765533072, COSV56676988; called by muse, mutect2, varscan2
- SPON1 | c.698C>T p.A233V | Missense Mutation (SNP) | VAF 83/220 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs1554927966, COSV59969549; called by muse, mutect2, varscan2
- SPRING1 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 104/230 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs770784378; called by muse, mutect2, varscan2
- SPSB1 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 313/692 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.102); catalogued as rs769406033, COSV60162164; called by muse, mutect2, varscan2
- SRCAP | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 222/481 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748556220, COSV52669024; called by muse, mutect2, varscan2
- SREK1 | c.893del p.N298Tfs*54 | Frame Shift Del (DEL) | VAF 112/302 reads (37%) | catalogued as COSV52331946; called by mutect2, pindel, varscan2
- SRRM1 | c.1279C>T p.R427C | Missense Mutation (SNP) | VAF 157/363 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs371315372; called by muse, mutect2, varscan2
- SSTR1 | c.254G>A p.R85H | Missense Mutation (SNP) | VAF 262/480 reads (55%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.663); catalogued as COSV57456694, COSV99942871; called by muse, mutect2, varscan2
- STAT6 | c.1153G>A p.A385T | Missense Mutation (SNP) | VAF 169/356 reads (47%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.999); catalogued as rs1362707029, COSV55673865; called by muse, mutect2, varscan2
- STAU2 | c.872G>A p.R291H (on ENST00000524300 / NM_001164380.2; = p.R259H on NM_014393.2) | Missense Mutation (SNP) | VAF 72/168 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs749339080, COSV63307155; called by muse, mutect2, varscan2
- STIMATE | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 194/384 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.117); catalogued as rs747256275; called by muse, mutect2, varscan2
- STING1 | c.694C>T p.H232Y | Missense Mutation (SNP) | VAF 122/301 reads (41%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs767228149, COSV58172536; called by mutect2, varscan2
- STK11 | c.881C>T p.P294L | Missense Mutation (SNP) | VAF 299/572 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV58823474; called by muse, mutect2, varscan2
- STXBP5L | c.3035G>A p.R1012H | Missense Mutation (SNP) | VAF 103/203 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368291652; called by muse, mutect2, varscan2
- SUMO3 | c.110C>T p.T37M | Missense Mutation (SNP) | VAF 310/670 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.901); catalogued as rs1482161206, COSV60538290; called by muse, mutect2, varscan2
- SUN1 | c.1136C>T p.T379M (on ENST00000405266 / NM_001367651.1; = p.T259M on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 133/297 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.163); catalogued as rs544208812, COSV61777614; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SUPT5H | c.2486C>T p.P829L | Missense Mutation (SNP) | VAF 350/712 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs368525453; called by muse, mutect2, varscan2
- SUV39H1 | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 21/327 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV61920808; called by muse, mutect2
- SYDE1 | c.529C>T p.R177W | Missense Mutation (SNP) | VAF 392/768 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100720654; called by muse, varscan2
- SZT2 | c.8811del p.S2938Hfs*41 (on ENST00000634258 / NM_001365999.1; = p.S2881Hfs*41 on NM_015284.4) | Frame Shift Del (DEL) | VAF 188/497 reads (38%) | catalogued as rs745420974; called by mutect2, pindel, varscan2
- TAF6 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 144/320 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as COSV59841929; called by muse, mutect2, varscan2
- TAL1 | c.185del p.G62Afs*13 | Frame Shift Del (DEL) | VAF 339/860 reads (39%) | catalogued as rs1289673879; called by mutect2, pindel, varscan2
- TANC2 | c.1546C>T p.R516W | Missense Mutation (SNP) | VAF 109/231 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs552429950, COSV67337015; called by muse, mutect2, varscan2
- TBC1D4 | c.847G>C p.G283R | Missense Mutation (SNP) | VAF 302/687 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.022); catalogued as COSV66488289; called by muse, mutect2, varscan2
- TCEAL9 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 97/97 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV65489186; called by muse, mutect2, varscan2
- TDRD15 | c.395T>C p.V132A | Missense Mutation (SNP) | VAF 97/246 reads (39%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs1197203562, COSV68267243; called by muse, mutect2, varscan2
- TECPR1 | c.2690+1G>A p.X897_splice | Splice Site (SNP) | VAF 201/451 reads (45%) | catalogued as rs866084981; called by muse, mutect2, varscan2
- TEK | c.319C>T p.R107* | Nonsense Mutation (SNP) | VAF 18/186 reads (10%) | catalogued as COSV66227903; called by muse, mutect2
- TENM3 | c.3409C>T p.Q1137* | Nonsense Mutation (SNP) | VAF 76/278 reads (27%) | catalogued as COSV101305070; called by muse, mutect2, varscan2
- TENM4 | c.7948T>A p.S2650T | Missense Mutation (SNP) | VAF 277/532 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs1321794105; called by muse, mutect2, varscan2
- TEPSIN | c.1355dup p.T453Hfs*43 | Frame Shift Ins (INS) | VAF 305/638 reads (48%) | catalogued as rs778951712; called by mutect2, varscan2
- TGFBR1 | c.1135A>G p.M379V | Missense Mutation (SNP) | VAF 91/181 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1554702207, CM063197; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TGFBRAP1 | c.2533G>A p.A845T | Missense Mutation (SNP) | VAF 157/383 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs139792932, COSV99305007; called by muse, mutect2, varscan2
- TGIF1 | c.187T>A p.C63S (on ENST00000330513 / NM_001374396.1; = p.C83S on NM_003244.4) | Missense Mutation (SNP) | VAF 147/306 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.607); catalogued as COSV57909329; called by muse, mutect2
- THBD | c.1435G>A p.D479N | Missense Mutation (SNP) | VAF 348/790 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs772287168; called by muse, mutect2
- THBS3 | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 239/535 reads (45%) | catalogued as rs552940002, COSV57425625; called by muse, mutect2, varscan2
- THSD1 | c.1301C>T p.T434M | Missense Mutation (SNP) | VAF 217/485 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs756442008; called by muse, mutect2, varscan2
- THSD7A | c.1342C>T p.R448C | Missense Mutation (SNP) | VAF 255/521 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs535672503, COSV70267019; called by muse, mutect2, varscan2
- TIA1 | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 105/213 reads (49%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.212); catalogued as rs371200431; called by muse, mutect2, varscan2
- TIMP4 | c.664G>A p.V222I | Missense Mutation (SNP) | VAF 26/293 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs748722586; called by muse, mutect2
- TLK2 | c.1547G>A p.R516Q (on ENST00000326270 / NM_001284333.2; = p.R494Q on NM_006852.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 138/282 reads (49%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.804); catalogued as rs753799200, COSV58299855; called by muse, mutect2, varscan2
- TMEM132A | c.1480del p.L494Cfs*82 (on ENST00000453848 / NM_178031.3; = p.L495Cfs*82 on NM_017870.4) | Frame Shift Del (DEL) | VAF 364/993 reads (37%) | catalogued as COSV50001098; called by mutect2, pindel, varscan2
- TMEM132C | c.2717G>A p.S906N | Missense Mutation (SNP) | VAF 280/635 reads (44%) | SIFT tolerated (0.76); PolyPhen benign (0.137); catalogued as rs751399839; called by muse, mutect2, varscan2
- TMEM161B | c.296A>G p.H99R | Missense Mutation (SNP) | VAF 97/180 reads (54%) | SIFT tolerated (1); PolyPhen probably damaging (0.987); catalogued as rs1352333400; called by muse, varscan2
- TMEM200C | c.505G>A p.G169R | Missense Mutation (SNP) | VAF 208/439 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67309157; called by muse, mutect2, varscan2
- TMEM63B | c.2038del p.A680Lfs*2 | Frame Shift Del (DEL) | VAF 260/646 reads (40%) | catalogued as COSV52477603; called by mutect2, pindel, varscan2
- TMEM74 | c.719C>T p.T240M | Missense Mutation (SNP) | VAF 240/502 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52464262; called by muse, varscan2
- TMEM79 | c.800T>C p.L267P | Missense Mutation (SNP) | VAF 241/486 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.074); catalogued as rs750272261; called by muse, mutect2, varscan2
- TMPRSS5 | c.1253G>A p.R418H | Missense Mutation (SNP) | VAF 297/681 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0.009); catalogued as rs771746689; called by muse, mutect2, varscan2
- TMUB2 | c.865C>T p.R289* (on ENST00000538716 / NM_001353177.2; = p.R269* on NM_024107.3 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 198/396 reads (50%) | catalogued as rs540365819, COSV100116029; called by muse, mutect2, varscan2
- TNFRSF25 | c.1184C>T p.A395V | Missense Mutation (SNP) | VAF 68/834 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs567034403, COSV61068564; called by muse, mutect2
- TNFSF9 | c.352G>A p.V118M | Missense Mutation (SNP) | VAF 200/493 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1380993370, COSV99832386; called by muse, mutect2, varscan2
- TNIP1 | c.1430G>A p.R477H | Missense Mutation (SNP) | VAF 183/398 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59303670; called by muse, mutect2, varscan2
- TNK1 | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 219/453 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs567049969; called by muse, mutect2, varscan2
- TNK2 | c.1522dup p.Q508Pfs*12 | Frame Shift Ins (INS) | VAF 92/205 reads (45%) | catalogued as rs754147115; called by mutect2, varscan2
- TNKS | c.1375G>A p.A459T | Missense Mutation (SNP) | VAF 174/334 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1385685971; called by muse, varscan2
- TNRC18 | c.6053C>T p.A2018V | Missense Mutation (SNP) | VAF 352/752 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as rs1362180154; called by muse, mutect2, varscan2
- TNRC6B | c.2551G>A p.V851I | Missense Mutation (SNP) | VAF 318/619 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.044); catalogued as rs371566608; called by muse, mutect2, varscan2
- TONSL | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 307/607 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs145310042; called by muse, mutect2, varscan2
- TPO | c.611del p.P204Rfs*5 | Frame Shift Del (DEL) | VAF 172/441 reads (39%) | catalogued as COSV100219300; called by mutect2, pindel, varscan2
- TPTE | c.1310T>C p.M437T (on ENST00000618007 / NM_199261.4; = p.M419T on NM_199259.4) | Missense Mutation (SNP) | VAF 43/316 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.055); catalogued as rs781224316; called by muse, mutect2, varscan2
- TRABD2B | c.532G>A p.V178M | Missense Mutation (SNP) | VAF 299/611 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1457878912; called by muse, mutect2, varscan2
- TRIM46 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 334/687 reads (49%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.484); catalogued as rs771891407; called by muse, mutect2, varscan2
- TRMT112 | c.46del p.V16Wfs*30 | Frame Shift Del (DEL) | VAF 283/722 reads (39%) | catalogued as rs762738556, COSV50008423; called by mutect2, pindel, varscan2
- TRMT9B | c.778A>G p.T260A | Missense Mutation (SNP) | VAF 80/264 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs772251263; called by muse, mutect2, varscan2
- TRPC4 | c.905C>T p.A302V | Missense Mutation (SNP) | VAF 120/245 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV100156725; called by muse, mutect2, varscan2
- TRPM2 | c.4411G>A p.A1471T | Missense Mutation (SNP) | VAF 257/599 reads (43%) | SIFT tolerated (0.59); PolyPhen benign (0.022); catalogued as rs200160241; called by muse, mutect2, varscan2
- TRPV3 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 281/626 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.121); catalogued as rs771754404; called by muse, mutect2, varscan2
- TSC2 | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 133/345 reads (39%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.995); catalogued as rs755631210, COSV54755492; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- TSHZ1 | c.1064C>T p.A355V (on ENST00000580243 / NM_001308210.2; = p.A310V on NM_005786.6) | Missense Mutation (SNP) | VAF 268/660 reads (41%) | SIFT tolerated (0.44); PolyPhen benign (0.031); catalogued as rs774253030, COSV59010082; called by muse, mutect2, varscan2
- TSPOAP1 | c.2094del p.F698Lfs*18 | Frame Shift Del (DEL) | VAF 102/239 reads (43%) | catalogued as rs1567845269; called by mutect2, pindel, varscan2
- TSPOAP1 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 206/470 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs761494665; called by muse, mutect2, varscan2
- TTC21A | c.3292_3294del p.K1098del | In Frame Del (DEL) | VAF 162/358 reads (45%) | catalogued as rs749001008; called by pindel, varscan2
- TTC7A | c.124C>T p.P42S | Missense Mutation (SNP) | VAF 352/744 reads (47%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs865919847; called by muse, mutect2, varscan2
- TTK | c.2571del p.K857Nfs*36 | Frame Shift Del (DEL) | VAF 58/138 reads (42%) | catalogued as rs768996038, COSV57882295; called by mutect2, varscan2
- TTLL2 | c.1450C>T p.P484S | Missense Mutation (SNP) | VAF 134/367 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0.023); catalogued as rs142723528; called by muse, mutect2, varscan2
- TTN | c.102469C>T p.P34157S (on ENST00000591111; = p.P26733S on NM_003319.4) | Missense Mutation (SNP) | VAF 82/185 reads (44%) | PolyPhen possibly damaging (0.776); catalogued as rs780544430; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.100168G>A p.V33390M (on ENST00000591111; = p.V25966M on NM_003319.4) | Missense Mutation (SNP) | VAF 180/364 reads (49%) | PolyPhen possibly damaging (0.855); catalogued as rs552058608; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.43157G>A p.R14386H (on ENST00000591111; = p.R6962H on NM_003319.4) | Missense Mutation (SNP) | VAF 130/351 reads (37%) | PolyPhen probably damaging (0.998); catalogued as rs757013471, COSV59980107; called by muse, mutect2, varscan2
- TTN | c.3616G>T p.A1206S (on ENST00000591111; = p.A1160S on NM_003319.4) | Missense Mutation (SNP) | VAF 140/312 reads (45%) | PolyPhen possibly damaging (0.737); catalogued as rs200749662, COSV100606635; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUBA3D | c.108G>A p.M36I | Missense Mutation (SNP) | VAF 54/687 reads (8%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.013); catalogued as rs1433007288, COSV58313421; called by muse, mutect2
- UBE2S | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 403/878 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1415815212; called by muse, mutect2, varscan2
- UBR1 | c.1379A>G p.N460S | Missense Mutation (SNP) | VAF 191/331 reads (58%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.475); catalogued as rs779007025, COSV99317565; called by muse, mutect2, varscan2
- UNC13C | c.3481G>A p.E1161K | Missense Mutation (SNP) | VAF 165/287 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as rs201440683, COSV99514876; called by muse, mutect2, varscan2
- UNC13D | c.68G>A p.R23H | Missense Mutation (SNP) | VAF 32/636 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs554971343, COSV99257116; called by muse, mutect2
- UNC5B | c.1156G>A p.V386M | Missense Mutation (SNP) | VAF 58/840 reads (7%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.595); catalogued as rs780781213, COSV58978916; called by muse, mutect2
- UNC93B1 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 242/470 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as rs754100504, COSV57098392; called by muse, mutect2, varscan2
- USP53 | c.545G>A p.R182Q | Missense Mutation (SNP) | VAF 138/321 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.687); catalogued as rs369528279; called by muse, mutect2
- VLDLR | c.212C>T p.T71M | Missense Mutation (SNP) | VAF 113/229 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs575202021, COSV66074290; called by muse, mutect2, varscan2
- VNN2 | c.970G>A p.A324T | Missense Mutation (SNP) | VAF 110/283 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.174); catalogued as rs775468896; called by muse, varscan2
- VPS11 | c.83G>A p.R28Q (on ENST00000620429; = p.R572Q on NM_021729.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 144/424 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as rs782181611; called by muse, mutect2, varscan2
- VPS18 | c.2134G>A p.A712T | Missense Mutation (SNP) | VAF 443/764 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1379694371; called by muse, mutect2, varscan2
- VPS51 | c.625G>A p.V209M | Missense Mutation (SNP) | VAF 332/919 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs137860347; called by muse, mutect2, varscan2
1,316 further variants in this file (782 protein-altering or splice-affecting, 453 silent, 81 other) are not listed here.
